Somatic mutation profile of tumor specimen C3L-04207-01 (aliquot CPT0325690013) from CPTAC case C3L-04207, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 82.5 years (30,121 days).
Specimen C3L-04207-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Head & Neck; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a62808e7-8432-4f75-861d-d048c6bc20a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04207-31 (Blood Derived Normal), aliquot CPT0326360002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/22c4518b-73b5-447c-99c7-429dc0cfaa8a

The open-access MAF lists 2,018 somatic variants for this specimen: 1,314 protein-altering or splice-affecting, 633 silent, 71 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,206, Silent 633, Nonsense Mutation 68, Intron 42, Splice Region 15, Frame Shift Del 12, 5'Flank 11, 3'UTR 8, RNA 7, Splice Site 6, In Frame Del 3, 5'UTR 2.

Variants (750 of 2,018; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDK4 | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 116/346 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs104894340, CM980320, COSV56983700, COSV56984378; ClinVar: pathogenic / risk factor / likely pathogenic; called by muse, mutect2, varscan2
- GJB3 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 191/681 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.021); catalogued as rs1028370381, CM041011, COSV64904760; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NF1 | c.4333-1G>A p.X1445_splice (on ENST00000358273 / NM_001042492.3; = p.X1424_splice on NM_000267.3) | Splice Site (SNP) | VAF 64/269 reads (24%) | catalogued as rs1418965797, CS1311526, CS163217; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- OXA1L | c.169C>T p.L57F | Missense Mutation (SNP) | VAF 125/446 reads (28%) | hotspot (GDC flag); SIFT tolerated, low confidence (0.11); PolyPhen benign (0.208); catalogued as rs773412250, COSV53536555; called by muse, mutect2, varscan2
- PCSK9 | c.1394C>T p.S465L | Missense Mutation (SNP) | VAF 156/676 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as rs778849441, CM1514511; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2
- SCN5A | c.4886G>A p.R1629Q (on ENST00000333535 / NM_198056.3; = p.R1628Q on NM_000335.5) | Missense Mutation (SNP) | VAF 157/542 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs199473623, CM100748, COSV61115745; ClinVar: not provided / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AADAC | c.488C>T p.A163V | Missense Mutation (SNP) | VAF 107/438 reads (24%) | SIFT tolerated (0.82); PolyPhen benign (0.02); catalogued as rs754536788; called by muse, mutect2, varscan2
- ABCA4 | c.1344G>A p.M448I | Missense Mutation (SNP) | VAF 33/257 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as CD991545; called by muse, mutect2, varscan2
- ABCD2 | c.1970C>T p.S657F | Missense Mutation (SNP) | VAF 86/327 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as rs1405641865, COSV104394064; called by muse, mutect2, varscan2
- AC007040.2 | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 170/488 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99730675; called by muse, mutect2, varscan2
- AC007040.2 | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 169/486 reads (35%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as COSV99730372; called by muse, mutect2, varscan2
- AC008676.3 | c.250C>T p.P84S | Missense Mutation (SNP) | VAF 165/593 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV56637073, COSV56638099; called by muse, mutect2, varscan2
- AC127029.3 | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 140/740 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs373958758; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACSM4 | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 74/370 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.232); catalogued as COSV68066569; called by muse, mutect2, varscan2
- ACSM5 | c.1603G>A p.E535K | Missense Mutation (SNP) | VAF 117/343 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV59374875; called by muse, mutect2, varscan2
- ADA | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 180/587 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.031); catalogued as rs1413219982; called by muse, mutect2, varscan2
- ADAM28 | c.1952G>A p.W651* | Nonsense Mutation (SNP) | VAF 83/429 reads (19%) | catalogued as rs751965692; called by muse, mutect2, varscan2
- ADAM29 | c.1451G>A p.G484E | Missense Mutation (SNP) | VAF 109/379 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63661589; called by muse, mutect2, varscan2
- ADAMTS20 | c.5609G>A p.G1870E | Missense Mutation (SNP) | VAF 98/322 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67125977; called by muse, mutect2, varscan2
- ADAMTS4 | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 117/525 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.044); catalogued as COSV100917581; called by muse, mutect2, varscan2
- ADCY8 | c.1172C>T p.T391I | Missense Mutation (SNP) | VAF 196/484 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.042); catalogued as rs1175489269; called by muse, mutect2, varscan2
- ADGRF5 | c.3002C>T p.S1001F | Missense Mutation (SNP) | VAF 132/454 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as COSV51942097; called by muse, mutect2, varscan2
- ADGRF5 | c.1493A>G p.N498S | Missense Mutation (SNP) | VAF 114/439 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.092); catalogued as rs757352384; called by muse, mutect2, varscan2
- ADGRG7 | c.2024C>T p.S675F | Missense Mutation (SNP) | VAF 80/353 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99841789; called by muse, mutect2, varscan2
- ADGRL2 | c.2264C>T p.S755L (on ENST00000370717 / NM_001366005.1; = p.S742L on NM_012302.4) | Missense Mutation (SNP) | VAF 93/416 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.347); catalogued as COSV54657880; called by muse, mutect2, varscan2
- ADGRV1 | c.6778C>T p.R2260* | Nonsense Mutation (SNP) | VAF 90/358 reads (25%) | catalogued as rs779821643, COSV67977499; called by muse, mutect2, varscan2
- ADH1C | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 72/355 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.763); catalogued as rs750873906, COSV72463652; called by muse, mutect2, varscan2
- AIFM3 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 152/486 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as rs748513370, COSV58999518; called by muse, mutect2, varscan2
- AK8 | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 166/566 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773353352; called by muse, mutect2, varscan2
- AKAP6 | c.5141C>T p.S1714L | Missense Mutation (SNP) | VAF 106/339 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs143719716, COSV55208499, COSV55218311; called by muse, mutect2, varscan2
- AKR1D1 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 134/542 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs779758762, COSV54339065; called by muse, varscan2
- ALDH5A1 | c.1493C>T p.S498F | Missense Mutation (SNP) | VAF 123/496 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as rs867032162, COSV62372820; called by muse, mutect2, varscan2
- ALMS1 | c.3700C>T p.P1234S | Missense Mutation (SNP) | VAF 145/468 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs777259139; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALOX15B | c.1495G>A p.D499N | Missense Mutation (SNP) | VAF 74/215 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.914); catalogued as rs772792324, COSV101205670; called by muse, mutect2, varscan2
- ALPK1 | c.2206C>T p.P736S | Missense Mutation (SNP) | VAF 132/487 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.284); catalogued as rs752279606; called by muse, mutect2, varscan2
- AMER1 | c.899C>T p.P300L | Missense Mutation (SNP) | VAF 109/646 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as COSV57664483; called by muse, mutect2, varscan2
- ANHX | c.674A>G p.N225S | Missense Mutation (SNP) | VAF 142/518 reads (27%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs1226563772; called by muse, mutect2
- ANKFN1 | c.1126G>A p.D376N | Missense Mutation (SNP) | VAF 176/432 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1483775741, COSV59457299; called by muse, mutect2, varscan2
- ANKRD1 | c.590G>A p.G197E | Missense Mutation (SNP) | VAF 133/367 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV65468146; called by muse, mutect2, varscan2
- ANKRD30A | c.3598C>T p.P1200S (on ENST00000611781; = p.P1144S on NM_052997.2) | Missense Mutation (SNP) | VAF 74/258 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs776058849, COSV100653526; called by muse, mutect2, varscan2
- ANO2 | c.893C>A p.S298Y (on ENST00000356134 / NM_001278597.3; = p.S302Y on NM_001278596.3) | Missense Mutation (SNP) | VAF 34/426 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.281); catalogued as COSV59012520; called by muse, mutect2
- ANO4 | c.925C>T p.R309* (on ENST00000392977 / NM_001286615.2; = p.R274* on NM_178826.4) | Nonsense Mutation (SNP) | VAF 100/334 reads (30%) | catalogued as rs866684439, COSV104407411, COSV54586554; called by muse, mutect2, varscan2
- APP | c.491A>G p.N164S | Missense Mutation (SNP) | VAF 39/273 reads (14%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as rs1231783932; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AQP6 | c.773G>A p.G258E | Missense Mutation (SNP) | VAF 158/618 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59645716; called by muse, mutect2, varscan2
- ARAP3 | c.4535C>T p.P1512L | Missense Mutation (SNP) | VAF 155/514 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.188); catalogued as rs1359684631; called by muse, mutect2, varscan2
- ARHGAP22 | c.1901G>A p.R634Q | Missense Mutation (SNP) | VAF 52/321 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374843400, COSV50932392; called by muse, mutect2, varscan2
- ARHGAP32 | c.4171C>T p.R1391W (on ENST00000310343 / NM_001378025.1; = p.R1042W on NM_014715.4) | Missense Mutation (SNP) | VAF 267/559 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs371744455; called by muse, mutect2, varscan2
- ARHGEF28 | c.568C>T p.Q190* | Nonsense Mutation (SNP) | VAF 178/474 reads (38%) | catalogued as COSV55261925; called by muse, mutect2, varscan2
- ARID2 | c.1480C>T p.H494Y | Missense Mutation (SNP) | VAF 93/311 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.09); catalogued as rs1318427003; called by muse, mutect2, varscan2
- ARMH1 | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 68/568 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs1200498483; called by muse, varscan2
- ARMH1 | c.859C>T p.L287F | Missense Mutation (SNP) | VAF 152/574 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as rs766949440; called by muse, varscan2
- ASB10 | c.52G>A p.D18N | Missense Mutation (SNP) | VAF 133/520 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as rs990376377; called by muse, mutect2, varscan2
- ASB11 | c.841C>T p.R281C | Missense Mutation (SNP) | VAF 104/282 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs773871027; called by muse, mutect2
- ASTN1 | c.3859G>A p.D1287N | Missense Mutation (SNP) | VAF 126/386 reads (33%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs760721420, COSV62495360; called by muse, mutect2, varscan2
- ASXL3 | c.6319G>A p.E2107K | Missense Mutation (SNP) | VAF 116/476 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs868143730, COSV52466971; called by muse, mutect2, varscan2
- ATP2B4 | c.3338C>T p.S1113F | Missense Mutation (SNP) | VAF 59/313 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV58176706; called by muse, mutect2, varscan2
- ATP6V0A2 | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 90/234 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.071); catalogued as COSV57749602; called by muse, mutect2, varscan2
- B4GALNT2 | c.1364G>A p.G455E | Missense Mutation (SNP) | VAF 266/629 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1489404226, COSV55928231; called by muse, mutect2, varscan2
- BAIAP3 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 54/385 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as rs1315741593; called by muse, mutect2, varscan2
- C10orf120 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 53/361 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as rs1364562174, COSV100271756; called by muse, mutect2, varscan2
- C10orf71 | c.2485G>T p.E829* | Nonsense Mutation (SNP) | VAF 78/487 reads (16%) | catalogued as COSV100110199; called by muse, mutect2, varscan2
- C12orf42 | c.307C>T p.H103Y | Missense Mutation (SNP) | VAF 107/378 reads (28%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1354629031, COSV59382911; called by muse, mutect2, varscan2
- C1orf94 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 101/470 reads (21%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs1214589775, COSV64915708; called by muse, mutect2, varscan2
- C2orf16 | c.101G>A p.R34K | Missense Mutation (SNP) | VAF 132/421 reads (31%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.003); catalogued as rs1312564412; called by muse, mutect2, varscan2
- C2orf81 | c.1736C>T p.P579L | Missense Mutation (SNP) | VAF 106/389 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.161); catalogued as rs1225754891; called by muse, mutect2, varscan2
- C4B | c.3352C>T p.Q1118* | Nonsense Mutation (SNP) | VAF 170/652 reads (26%) | catalogued as COSV101312145; called by muse, mutect2, varscan2
- C4orf51 | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 88/393 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as rs754400840; called by muse, mutect2, varscan2
- C6 | c.2416G>T p.D806Y | Missense Mutation (SNP) | VAF 104/422 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.827); catalogued as rs771548794; called by muse, mutect2, varscan2
- C6orf15 | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 156/606 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.276); catalogued as COSV52537412; called by muse, mutect2
- C6orf15 | c.302C>T p.S101L | Missense Mutation (SNP) | VAF 300/984 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.243); catalogued as rs547282944, COSV52538628; called by muse, mutect2, varscan2
- C8A | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 44/508 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as rs777495880, COSV63483150; called by muse, mutect2
- C8B | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 99/319 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs866652259, COSV64780233; called by muse, mutect2, varscan2
- C8orf34 | c.1463C>T p.S488F | Missense Mutation (SNP) | VAF 85/283 reads (30%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as rs867519093, COSV57407310; called by muse, mutect2, varscan2
- CACNA1C | c.2605G>A p.E869K | Missense Mutation (SNP) | VAF 77/484 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.952); catalogued as COSV59707593; called by muse, mutect2, varscan2
- CAMSAP1 | c.3427C>G p.R1143G | Missense Mutation (SNP) | VAF 218/792 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as COSV56722221; called by muse, mutect2, varscan2
- CAND1 | c.3437T>G p.V1146G | Missense Mutation (SNP) | VAF 83/345 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV101607369; called by muse, mutect2, varscan2
- CBL | c.1096-1G>A p.X366_splice | Splice Site (SNP) | VAF 43/107 reads (40%) | catalogued as CD1314297, CS099550, CS150637, COSV50631547, COSV50635311, COSV50641081; called by muse, mutect2, varscan2
- CBL | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1245863855, COSV50657369, COSV50665310; called by muse, mutect2, varscan2
- CBLC | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 203/798 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV54322260; called by muse, mutect2, varscan2
- CCDC180 | c.2146C>T p.Q716* | Nonsense Mutation (SNP) | VAF 113/458 reads (25%) | catalogued as COSV63835504; called by muse, mutect2, varscan2
- CCDC40 | c.2081C>T p.T694I | Missense Mutation (SNP) | VAF 315/673 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs1257892727; called by muse, mutect2, varscan2
- CCDC60 | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 102/346 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59545358; called by muse, mutect2, varscan2
- CD163L1 | c.2540G>A p.G847E | Missense Mutation (SNP) | VAF 104/388 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV58010794, COSV58025502; called by muse, mutect2, varscan2
- CD163L1 | c.2048C>T p.S683F | Missense Mutation (SNP) | VAF 86/274 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100549805, COSV58022236; called by muse, mutect2, varscan2
- CD1B | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 85/324 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs747786661, COSV63803744; called by muse, mutect2, varscan2
- CD44 | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 37/256 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as rs916847375; called by muse, mutect2, varscan2
- CDH10 | c.865G>A p.G289R | Missense Mutation (SNP) | VAF 136/444 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52598229; called by muse, mutect2, varscan2
- CDH15 | c.2062C>T p.R688C | Missense Mutation (SNP) | VAF 142/487 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747232960, COSV57028485; called by muse, mutect2, varscan2
- CDH16 | c.490C>T p.R164* | Nonsense Mutation (SNP) | VAF 63/522 reads (12%) | catalogued as COSV55335750; called by muse, mutect2, varscan2
- CDH18 | c.2192C>T p.P731L | Missense Mutation (SNP) | VAF 161/610 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56935463; called by muse, mutect2, varscan2
- CDH8 | c.509G>A p.G170E | Missense Mutation (SNP) | VAF 122/369 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV104408088, COSV54845824; called by muse, mutect2, varscan2
- CELSR2 | c.3712G>A p.E1238K | Missense Mutation (SNP) | VAF 176/442 reads (40%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.91); catalogued as rs1328807117; called by muse, mutect2
- CELSR3 | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 207/698 reads (30%) | catalogued as COSV50840505; called by muse, mutect2, varscan2
- CENPF | c.1886T>C p.L629P | Missense Mutation (SNP) | VAF 94/315 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs928746742; called by muse, mutect2, varscan2
- CEP126 | c.2384G>A p.G795E | Missense Mutation (SNP) | VAF 2367/2582 reads (92%) | SIFT tolerated (0.06); PolyPhen benign (0.403); catalogued as rs770830961; called by muse, mutect2, varscan2
- CEP192 | c.6216C>A p.F2072L | Missense Mutation (SNP) | VAF 93/398 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.035); catalogued as COSV100381106; called by muse, mutect2, varscan2
- CEP350 | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 77/427 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1275522303, COSV62485769, COSV62486106; called by muse, mutect2, varscan2
- CFAP20DC | c.968G>A p.G323E (on ENST00000482387 / NM_001351530.2; = p.G198E on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 106/363 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.781); catalogued as COSV55928083; called by muse, mutect2, varscan2
- CFAP61 | c.3217G>A p.G1073S | Missense Mutation (SNP) | VAF 64/229 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1454108921; called by muse, mutect2, varscan2
- CFAP69 | c.2167T>C p.Y723H | Missense Mutation (SNP) | VAF 68/336 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1223643724; called by muse, mutect2, varscan2
- CFTR | c.1418G>A p.G473E | Missense Mutation (SNP) | VAF 109/358 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD972126, COSV50045021; called by muse, mutect2, varscan2
- CGB2 | c.464C>T p.P155L | Missense Mutation (SNP) | VAF 96/605 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as COSV99041398; called by muse, mutect2, varscan2
- CGN | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 116/503 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373995070; called by muse, mutect2, varscan2
- CHD6 | c.4391C>T p.S1464F | Missense Mutation (SNP) | VAF 120/405 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV64689389; called by muse, mutect2, varscan2
- CHI3L1 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 126/455 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as rs758702728; called by muse, mutect2, varscan2
- CHRNB3 | c.1276C>A p.L426I | Missense Mutation (SNP) | VAF 114/504 reads (23%) | SIFT tolerated (0.76); PolyPhen probably damaging (0.999); catalogued as COSV51497128; called by muse, mutect2, varscan2
- CLCC1 | c.1231C>T p.P411S (on ENST00000356970 / NM_001377464.1; = p.P361S on NM_015127.5) | Missense Mutation (SNP) | VAF 82/520 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as rs979595726, COSV100206406; called by muse, mutect2, varscan2
- CLDN16 | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 83/351 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV99290316; called by muse, mutect2, varscan2
- CNBD2 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 76/272 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as rs200885142, COSV62586786; called by muse, mutect2, varscan2
- CNDP1 | c.1477A>G p.T493A | Missense Mutation (SNP) | VAF 99/353 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1324331208; called by muse, mutect2, varscan2
- COG6 | c.835C>T p.R279C | Missense Mutation (SNP) | VAF 92/361 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs764437648, COSV62997167; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL14A1 | c.2209G>A p.G737R | Missense Mutation (SNP) | VAF 124/327 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52848132, COSV52867096; called by muse, mutect2, varscan2
- COL21A1 | c.1886G>A p.G629E | Missense Mutation (SNP) | VAF 108/391 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1313458713, COSV55163585; called by muse, mutect2, varscan2
- COL22A1 | c.1870C>T p.P624S | Missense Mutation (SNP) | VAF 199/625 reads (32%) | SIFT tolerated (0.81); PolyPhen benign (0.042); catalogued as rs1319761353; called by muse, mutect2, varscan2
- COL25A1 | c.1155G>A p.G385= | Splice Region (SNP) | VAF 63/309 reads (20%) | catalogued as COSV67645795; called by muse, mutect2, varscan2
- COL4A1 | c.2375C>T p.S792F | Missense Mutation (SNP) | VAF 44/299 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.105); catalogued as rs1187779043, COSV65426100; called by muse, mutect2, varscan2
- COL5A1 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 124/508 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV65670041; called by muse, mutect2, varscan2
- COL7A1 | c.1043G>A p.R348Q | Missense Mutation (SNP) | VAF 130/468 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs200570283; called by muse, mutect2, varscan2
- COQ9 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 53/370 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.486); catalogued as rs1327256293, COSV52646189; called by muse, mutect2, varscan2
- CPD | c.1583C>T p.S528F | Missense Mutation (SNP) | VAF 69/424 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99853211; called by muse, varscan2
- CPQ | c.1310G>A p.G437E | Missense Mutation (SNP) | VAF 166/503 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55139733; called by muse, mutect2, varscan2
- CR2 | c.2935G>A p.G979S | Missense Mutation (SNP) | VAF 70/246 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.311); catalogued as rs1490877307; called by muse, mutect2, varscan2
- CRACDL | c.2362G>A p.E788K | Missense Mutation (SNP) | VAF 100/769 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.546); catalogued as COSV67409201; called by muse, mutect2, varscan2
- CRB1 | c.2528T>C p.L843P | Missense Mutation (SNP) | VAF 110/391 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.305); catalogued as COSV66329009; called by muse, mutect2, varscan2
- CROCC2 | c.2263G>A p.G755R | Missense Mutation (SNP) | VAF 118/490 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs1305579539; called by muse, mutect2, varscan2
- CSMD1 | c.3212C>T p.S1071F (on ENST00000520002; = p.S1070F on NM_033225.6) | Missense Mutation (SNP) | VAF 166/609 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as rs368592556, COSV59302376; called by muse, mutect2, varscan2
- CSMD2 | c.5563G>A p.G1855S | Missense Mutation (SNP) | VAF 94/446 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53952127; called by muse, mutect2, varscan2
- CSMD2 | c.4336G>A p.G1446R | Missense Mutation (SNP) | VAF 72/344 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1433283674; called by muse, mutect2, varscan2
- CSMD2 | c.3673G>A p.D1225N | Missense Mutation (SNP) | VAF 127/500 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as rs866303668; called by muse, mutect2, varscan2
- CSMD3 | c.9131C>T p.S3044L (on ENST00000297405 / NM_001363185.1; = p.S2875L on NM_052900.3) | Missense Mutation (SNP) | VAF 171/446 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.497); catalogued as rs757447141; called by muse, mutect2, varscan2
- CSMD3 | c.6508G>A p.G2170R (on ENST00000297405 / NM_001363185.1; = p.G2066R on NM_052900.3) | Missense Mutation (SNP) | VAF 110/517 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs963910114; called by muse, mutect2, varscan2
- CSMD3 | c.5521C>T p.P1841S (on ENST00000297405 / NM_001363185.1; = p.P1737S on NM_052900.3) | Missense Mutation (SNP) | VAF 117/331 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs768183010; called by muse, mutect2, varscan2
- CSNKA2IP | c.1270G>A p.G424S | Missense Mutation (SNP) | VAF 85/295 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as rs1238703173; called by muse, mutect2, varscan2
- CTPS2 | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 137/383 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV63724450; called by muse, mutect2, varscan2
- CXADR | c.734G>A p.G245E | Missense Mutation (SNP) | VAF 54/318 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs760582039, COSV53031716; called by muse, mutect2, varscan2
- CYLC2 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 117/485 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.069); catalogued as COSV66336461, COSV66339631; called by muse, mutect2, varscan2
- CYP19A1 | c.713C>T p.S238F | Missense Mutation (SNP) | VAF 87/316 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.4); catalogued as COSV99547887; called by muse, mutect2, varscan2
- CYP26B1 | c.1288C>T p.H430Y | Missense Mutation (SNP) | VAF 226/691 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.356); catalogued as rs766677136; called by muse, mutect2, varscan2
- DACH1 | c.1294C>T p.P432S (on ENST00000619232 / NM_001366712.1; = p.P380S on NM_080759.6) | Missense Mutation (SNP) | VAF 111/324 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs767288373, COSV57518979; called by muse, mutect2, varscan2
- DCAF1 | c.2828C>T p.P943L | Missense Mutation (SNP) | VAF 119/518 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.425); catalogued as COSV100245121, COSV60042663; called by muse, mutect2, varscan2
- DCC | c.2645C>T p.T882I | Missense Mutation (SNP) | VAF 129/431 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1568102148, COSV59135309; called by muse, mutect2, varscan2
- DCDC2 | c.1018G>A p.D340N | Missense Mutation (SNP) | VAF 94/368 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1389720008, COSV65829564; called by muse, mutect2, varscan2
- DCLK1 | c.2149G>A p.E717K (on ENST00000360631 / NM_001330072.2; = p.E410K on NM_001195416.2) | Missense Mutation (SNP) | VAF 169/478 reads (35%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.055); catalogued as COSV55174416; called by muse, mutect2, varscan2
- DDC | c.1108G>A p.G370R | Missense Mutation (SNP) | VAF 122/399 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63564028; called by muse, mutect2, varscan2
- DEFA3 | c.192G>A p.M64I | Missense Mutation (SNP) | VAF 152/458 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs867866667; called by muse, mutect2, varscan2
- DEPDC7 | c.554C>T p.S185F (on ENST00000241051 / NM_001077242.2; = p.S176F on NM_139160.2) | Missense Mutation (SNP) | VAF 54/317 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs777338685; called by muse, mutect2, varscan2
- DHRS13 | c.766C>T p.R256W | Missense Mutation (SNP) | VAF 97/505 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs773690240; called by muse, mutect2, varscan2
- DLC1 | c.2388G>T p.K796N (on ENST00000276297 / NM_001348081.2; = p.K359N on NM_006094.5) | Missense Mutation (SNP) | VAF 208/648 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.077); catalogued as COSV99363781; called by muse, mutect2
- DMD | c.6255G>A p.W2085* | Nonsense Mutation (SNP) | VAF 112/299 reads (37%) | catalogued as CM098433, COSV63774600; called by muse, mutect2, varscan2
- DNAH17 | c.6691G>A p.E2231K | Missense Mutation (SNP) | VAF 100/487 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778357087; called by muse, mutect2, varscan2
- DNAH5 | c.13560G>A p.W4520* | Nonsense Mutation (SNP) | VAF 143/543 reads (26%) | catalogued as COSV54224649; called by muse, mutect2, varscan2
- DNAH5 | c.7916G>A p.R2639Q | Missense Mutation (SNP) | VAF 115/362 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs140968268, COSV54202500; called by muse, mutect2, varscan2
- DNAH5 | c.1593G>A p.M531I | Missense Mutation (SNP) | VAF 89/361 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1216204013, COSV54225871; called by muse, mutect2, varscan2
- DNAH6 | c.1918G>A p.E640K | Missense Mutation (SNP) | VAF 66/231 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.313); catalogued as COSV52850534; called by muse, mutect2, varscan2
- DNAH6 | c.3457C>T p.R1153* | Nonsense Mutation (SNP) | VAF 114/339 reads (34%) | catalogued as rs201711823, COSV52883407; called by muse, mutect2, varscan2
- DNAH7 | c.3351G>A p.M1117I | Missense Mutation (SNP) | VAF 111/542 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.083); catalogued as COSV100415057; called by muse, mutect2, varscan2
- DNAH9 | c.3412G>A p.E1138K | Missense Mutation (SNP) | VAF 121/311 reads (39%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs866851408, COSV52343092; called by muse, mutect2, varscan2
- DNAI2 | c.562C>T p.Q188* | Nonsense Mutation (SNP) | VAF 139/609 reads (23%) | catalogued as rs1194460219, COSV56757166; called by muse, mutect2, varscan2
- DNAJB4 | c.386G>A p.G129D | Missense Mutation (SNP) | VAF 91/326 reads (28%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs749944596; called by muse, mutect2, varscan2
- DOCK3 | c.515C>T p.S172L | Missense Mutation (SNP) | VAF 107/391 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.075); catalogued as rs1019362298; called by muse, mutect2, varscan2
- DOCK6 | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 60/410 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs778304629; called by muse, mutect2, varscan2
- DPEP1 | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 54/386 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as rs750273023; called by muse, mutect2, varscan2
- DPYD | c.1633C>T p.P545S | Missense Mutation (SNP) | VAF 107/450 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64603724; called by muse, mutect2, varscan2
- DRD2 | c.1137C>T p.L379= | Splice Region (SNP) | VAF 146/289 reads (51%) | catalogued as rs752872204, COSV60763426; called by muse, mutect2, varscan2
- DROSHA | c.1090C>T p.R364C | Missense Mutation (SNP) | VAF 106/427 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs756537138, COSV60773172, COSV60779169; called by muse, mutect2, varscan2
- DSC3 | c.2313G>A p.M771I | Missense Mutation (SNP) | VAF 119/527 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs867992638, COSV64572539; called by muse, mutect2, varscan2
- DSCAM | c.2236C>T p.L746F | Missense Mutation (SNP) | VAF 60/310 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV68035939; called by muse, mutect2, varscan2
- DSG1 | c.2443C>T p.P815S | Missense Mutation (SNP) | VAF 117/455 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.03); catalogued as rs778980591, COSV99935678; called by muse, mutect2, varscan2
- DSG3 | c.1991G>A p.G664E | Missense Mutation (SNP) | VAF 127/447 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.338); catalogued as rs1361767559, COSV57124023; called by muse, mutect2, varscan2
- DYDC1 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 82/266 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs1347785749; called by muse, mutect2, varscan2
- DYNC2I1 | c.845C>T p.S282L | Missense Mutation (SNP) | VAF 124/552 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs201289477; called by muse, mutect2
- EGF | c.3538G>A p.E1180K | Missense Mutation (SNP) | VAF 132/519 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.036); catalogued as rs768479710, COSV54483010; called by muse, mutect2, varscan2
- ELAPOR1 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 126/321 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs752456350, COSV64046269; called by muse, mutect2, varscan2
- ELL2 | c.389C>T p.S130L | Missense Mutation (SNP) | VAF 119/400 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1179954313; called by muse, mutect2, varscan2
- ELP1 | c.2495C>T p.P832L | Missense Mutation (SNP) | VAF 73/308 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as rs1307998361, COSV65898423; called by muse, mutect2, varscan2
- ENPP1 | c.2380G>T p.V794F | Missense Mutation (SNP) | VAF 139/502 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV62932822; called by muse, mutect2, varscan2
- EPHA3 | c.2234G>A p.R745Q | Missense Mutation (SNP) | VAF 121/470 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs756739935, COSV60693553; called by muse, mutect2, varscan2
- EPO | c.571G>A p.G191R | Missense Mutation (SNP) | VAF 69/312 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as COSV99079054; called by muse, mutect2, varscan2
- ERC2 | c.1832G>A p.R611K | Missense Mutation (SNP) | VAF 112/422 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs267599909; called by muse, mutect2, varscan2
- ERICH3 | c.2630A>G p.E877G | Missense Mutation (SNP) | VAF 107/572 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV58614587; called by muse, mutect2, varscan2
- ERICH3 | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 54/230 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as rs778330322, COSV58600851; called by muse, mutect2, varscan2
- EXOC3L1 | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 63/440 reads (14%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.545); catalogued as rs1221683659; called by muse, mutect2, varscan2
- FAM13C | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 91/258 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.063); catalogued as COSV53246631; called by muse, mutect2, varscan2
- FAM171A1 | c.2638G>A p.E880K | Missense Mutation (SNP) | VAF 102/381 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100968604; called by muse, mutect2, varscan2
- FAM234B | c.393T>G p.D131E | Missense Mutation (SNP) | VAF 126/436 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.242); catalogued as rs1284536225; called by muse, mutect2, varscan2
- FAM47A | c.2194G>A p.D732N | Missense Mutation (SNP) | VAF 137/372 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as rs867405123, COSV60499777; called by muse, mutect2, varscan2
- FAM83B | c.1799C>T p.P600L | Missense Mutation (SNP) | VAF 136/504 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs753622094; called by muse, mutect2, varscan2
- FAM83H | c.662G>T p.G221V | Missense Mutation (SNP) | VAF 268/709 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101187071; called by muse, mutect2, varscan2
- FASN | c.5788C>T p.R1930C | Missense Mutation (SNP) | VAF 127/629 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs143560521, COSV60755362; called by muse, mutect2, varscan2
- FAT3 | c.453G>A p.M151I | Missense Mutation (SNP) | VAF 106/200 reads (53%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.57); catalogued as COSV53113655; called by muse, mutect2, varscan2
- FAT4 | c.12910G>A p.G4304S | Missense Mutation (SNP) | VAF 141/552 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs746761404, COSV58694307; called by muse, mutect2, varscan2
- FBXO42 | c.1591C>T p.P531S | Missense Mutation (SNP) | VAF 152/400 reads (38%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs779067946; called by muse, mutect2, varscan2
- FDCSP | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 84/295 reads (28%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.091); catalogued as rs146455356; called by muse, mutect2, varscan2
- FER1L6 | c.4505G>A p.G1502E | Missense Mutation (SNP) | VAF 128/569 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); catalogued as COSV67553020; called by muse, mutect2, varscan2
- FERMT1 | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 73/266 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144791466; called by muse, mutect2, varscan2
- FGF12 | c.304G>T p.D102Y (on ENST00000454309 / NM_021032.5; = p.D40Y on NM_004113.6) | Missense Mutation (SNP) | VAF 88/309 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV53153576, COSV53168571; called by muse, mutect2, varscan2
- FGFR1OP2 | c.83C>A p.S28Y | Missense Mutation (SNP) | VAF 95/396 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.756); catalogued as COSV57586498; called by muse, mutect2, varscan2
- FGFR2 | c.2122C>T p.P708S | Missense Mutation (SNP) | VAF 116/368 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV60644612; called by muse, varscan2
- FIGN | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 181/525 reads (34%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.992); catalogued as COSV60772354; called by muse, mutect2, varscan2
- FLG | c.4297G>A p.E1433K | Missense Mutation (SNP) | VAF 78/438 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as rs267598030, COSV64247369; called by muse, mutect2, varscan2
- FLT3 | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 82/303 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54070046; called by muse, mutect2, varscan2
- FMN2 | c.4154-1G>A p.X1385_splice | Splice Site (SNP) | VAF 56/349 reads (16%) | catalogued as rs755036020; called by muse, mutect2, varscan2
- FOXI1 | c.464A>G p.D155G | Missense Mutation (SNP) | VAF 180/654 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV60390208; called by muse, mutect2, varscan2
- FOXN1 | c.391C>T p.H131Y | Missense Mutation (SNP) | VAF 350/816 reads (43%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.04); catalogued as rs865864248; called by muse, mutect2, varscan2
- FPR3 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 58/438 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.145); catalogued as rs779072888, COSV59331000; called by muse, mutect2, varscan2
- FREM1 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 139/491 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.048); catalogued as rs568205611; called by muse, mutect2, varscan2
- FREM3 | c.1651G>A p.G551R | Missense Mutation (SNP) | VAF 170/545 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV61680068; called by muse, mutect2, varscan2
- FRMPD1 | c.3511G>A p.E1171K | Missense Mutation (SNP) | VAF 128/422 reads (30%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.04); catalogued as rs551468496; called by muse, varscan2
- FST | c.580C>T p.R194W | Missense Mutation (SNP) | VAF 150/504 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56815240; called by muse, mutect2, varscan2
- FSTL5 | c.2334G>A p.M778I | Missense Mutation (SNP) | VAF 99/463 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV60209996; called by muse, mutect2, varscan2
- G6PC2 | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 99/553 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs143670077; called by muse, mutect2, varscan2
- GABRA2 | c.614C>T p.S205L | Missense Mutation (SNP) | VAF 99/394 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV100734709; called by muse, mutect2, varscan2
- GABRG1 | c.178C>T p.H60Y | Missense Mutation (SNP) | VAF 134/459 reads (29%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as COSV54956622, COSV99777603; called by muse, mutect2, varscan2
- GADL1 | c.1363G>A p.G455R | Missense Mutation (SNP) | VAF 46/498 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.67); catalogued as rs779859861; called by muse, mutect2
- GAK | c.2692C>T p.P898S | Missense Mutation (SNP) | VAF 200/723 reads (28%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV100033097, COSV100033810; called by muse, mutect2, varscan2
- GALNS | c.719A>G p.Y240C | Missense Mutation (SNP) | VAF 43/324 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs752039956, CM1314343; called by muse, varscan2
- GALNT8 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 82/398 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.759); catalogued as rs777239325, COSV52895415, COSV99363168; called by muse, mutect2, varscan2
- GAREM1 | c.1483C>T p.P495S | Missense Mutation (SNP) | VAF 119/492 reads (24%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.769); catalogued as COSV52510841; called by muse, mutect2, varscan2
- GBP4 | c.787C>T p.H263Y | Missense Mutation (SNP) | VAF 88/410 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.793); catalogued as rs1419018949; called by muse, mutect2, varscan2
- GDF2 | c.1099G>A p.D367N | Missense Mutation (SNP) | VAF 65/445 reads (15%) | SIFT tolerated (0.76); PolyPhen benign (0.058); catalogued as rs782390220; called by muse, mutect2, varscan2
- GLRB | c.971C>T p.S324F | Missense Mutation (SNP) | VAF 137/511 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs868460883, COSV52413855, COSV52423095; called by muse, mutect2, varscan2
- GLYATL3 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 174/598 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs774013930; called by muse, mutect2, varscan2
- GOLGA6L2 | c.1742G>A p.G581E | Missense Mutation (SNP) | VAF 92/1570 reads (6%) | SIFT deleterious, low confidence (0.01); catalogued as rs1461586281, COSV61477092; called by muse, mutect2
- GOLGA8M | c.1777C>T p.P593S | Missense Mutation (SNP) | VAF 117/571 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1186295928; called by muse, mutect2, varscan2
- GOPC | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 96/338 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV50005030; called by muse, mutect2, varscan2
- GP6 | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 235/898 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.321); catalogued as rs866721211; called by muse, mutect2
- GPC5 | c.1121G>A p.R374K | Missense Mutation (SNP) | VAF 107/378 reads (28%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.484); catalogued as COSV100992275; called by muse, mutect2, varscan2
- GPR35 | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 166/553 reads (30%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.767); catalogued as rs756768919; called by muse, mutect2, varscan2
- GPRIN1 | c.2659C>T p.P887S | Missense Mutation (SNP) | VAF 263/769 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as rs1196806774; called by muse, mutect2, varscan2
- GRAMD1B | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 106/337 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.434); catalogued as rs895281458, COSV100455381; called by muse, mutect2, varscan2
- GRIA1 | c.2597G>A p.G866E | Missense Mutation (SNP) | VAF 156/504 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.138); catalogued as rs1340594187; called by muse, mutect2, varscan2
- GRIN2A | c.3217G>A p.E1073K | Missense Mutation (SNP) | VAF 154/498 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.122); catalogued as COSV58021321; called by muse, mutect2, varscan2
- GRIN2D | c.2094C>T p.F698= | Splice Region (SNP) | VAF 58/378 reads (15%) | catalogued as rs1476632057; called by muse, mutect2, varscan2
- GRM1 | c.2630G>A p.R877Q | Missense Mutation (SNP) | VAF 155/565 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as rs1298777355; called by muse, mutect2, varscan2
- GSDMA | c.550G>A p.G184R | Missense Mutation (SNP) | VAF 134/350 reads (38%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as COSV56978040; called by muse, mutect2, varscan2
- GTF3C1 | c.1289C>T p.S430F | Missense Mutation (SNP) | VAF 61/428 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62238905; called by muse, mutect2, varscan2
- HAPLN2 | c.577T>G p.W193G | Missense Mutation (SNP) | VAF 57/580 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99660897; called by muse, mutect2
- HDGFL1 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 184/692 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57753377; called by muse, mutect2, varscan2
- HERC1 | c.9022C>T p.R3008C | Missense Mutation (SNP) | VAF 177/547 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1259922239; called by muse, mutect2, varscan2
- HHLA2 | c.452G>A p.R151K | Missense Mutation (SNP) | VAF 123/463 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as rs973991506, COSV63320332; called by muse, mutect2, varscan2
- HIP1R | c.1930G>A p.D644N | Missense Mutation (SNP) | VAF 112/351 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.275); catalogued as rs776276941; called by muse, mutect2, varscan2
- HIVEP3 | c.5995C>T p.P1999S | Missense Mutation (SNP) | VAF 131/639 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV56017474; called by muse, mutect2, varscan2
- HLA-DMA | c.508G>A p.G170R | Missense Mutation (SNP) | VAF 230/850 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66386020; called by muse, mutect2, varscan2
- HMCN1 | c.16900C>T p.P5634S | Missense Mutation (SNP) | VAF 86/281 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54907290; called by muse, mutect2, varscan2
- HS3ST2 | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 80/524 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54458380; called by muse, mutect2, varscan2
- HS3ST4 | c.964G>A p.G322R | Missense Mutation (SNP) | VAF 87/491 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs780421499, COSV100501287; called by muse, mutect2, varscan2
- HS3ST4 | c.965G>A p.G322E | Missense Mutation (SNP) | VAF 87/496 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs751193517, COSV100502331; called by muse, mutect2, varscan2
- HYDIN | c.10465G>A p.G3489R | Missense Mutation (SNP) | VAF 53/341 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101159055; called by muse, mutect2, varscan2
- IARS1 | c.2291C>T p.S764F | Missense Mutation (SNP) | VAF 89/372 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as rs1489656391; called by muse, mutect2, varscan2
- IFNA21 | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 138/647 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as COSV66518632; called by muse, mutect2, varscan2
- IFT172 | c.4908T>G p.H1636Q | Missense Mutation (SNP) | VAF 78/394 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.532); catalogued as rs201840472; called by muse, mutect2, varscan2
- IGHD1-14 | c.14C>T p.T5I | Missense Mutation (SNP) | VAF 62/217 reads (29%) | PolyPhen possibly damaging (0.78); catalogued as rs782254661; called by muse, mutect2, varscan2
- IGHV6-1 | c.236G>A p.W79* | Nonsense Mutation (SNP) | VAF 95/338 reads (28%) | catalogued as rs781966393; called by muse, mutect2, varscan2
- IGSF1 | c.1037C>T p.P346L | Missense Mutation (SNP) | VAF 157/441 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as COSV63839936; called by muse, mutect2, varscan2
- IGSF10 | c.2167G>A p.E723K | Missense Mutation (SNP) | VAF 133/493 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as COSV56785588; called by muse, mutect2, varscan2
- IL12RB1 | c.1003C>T p.P335S | Missense Mutation (SNP) | VAF 133/350 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.371); catalogued as rs1433885521, COSV59098887; called by muse, mutect2, varscan2
- IL1RN | c.202G>A p.E68K (on ENST00000409930 / NM_173842.3; = p.E50K on NM_000577.5) | Missense Mutation (SNP) | VAF 113/326 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.255); catalogued as rs1357987243, COSV52080232; called by muse, mutect2, varscan2
- ING1 | c.971C>T p.A324V | Missense Mutation (SNP) | VAF 180/577 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.108); catalogued as COSV58167182; called by muse, mutect2, varscan2
- INTS2 | c.1313C>T p.A438V | Missense Mutation (SNP) | VAF 83/435 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52154513; called by muse, mutect2, varscan2
- IRF6 | c.650G>A p.W217* | Nonsense Mutation (SNP) | VAF 84/336 reads (25%) | catalogued as CM042372; called by muse, mutect2, varscan2
- ISM2 | c.1261C>T p.Q421* | Nonsense Mutation (SNP) | VAF 72/465 reads (15%) | catalogued as rs1226769303, COSV53634780; called by muse, mutect2, varscan2
- ITGA2B | c.2926C>T p.P976S | Missense Mutation (SNP) | VAF 219/579 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.864); catalogued as COSV52233307; called by muse, mutect2, varscan2
- ITGB3 | c.1990G>A p.E664K | Missense Mutation (SNP) | VAF 98/481 reads (20%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.457); catalogued as rs373150039; called by muse, mutect2, varscan2
- ITGBL1 | c.1148C>T p.S383F | Missense Mutation (SNP) | VAF 45/272 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.94); catalogued as COSV66012386; called by muse, mutect2, varscan2
- ITPR1 | c.4418C>T p.S1473L (on ENST00000354582; = p.S1458L on NM_002222.7) | Missense Mutation (SNP) | VAF 53/345 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs199530586; called by muse, mutect2, varscan2
- ITSN1 | c.329C>T p.S110F | Missense Mutation (SNP) | VAF 60/278 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV66084088; called by muse, mutect2, varscan2
- ITSN2 | c.1754C>T p.S585L | Missense Mutation (SNP) | VAF 48/256 reads (19%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.966); catalogued as COSV61944815; called by muse, mutect2, varscan2
- IVL | c.1309G>A p.E437K | Missense Mutation (SNP) | VAF 160/598 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as rs1406804545; called by muse, mutect2, varscan2
- JAG2 | c.1235C>T p.P412L | Missense Mutation (SNP) | VAF 58/369 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.446); catalogued as rs1444233637, COSV100077806; called by muse, mutect2, varscan2
- JAKMIP2 | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 80/334 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs934467542, COSV54599978; called by muse, mutect2, varscan2
- KANK1 | c.2933T>C p.M978T | Missense Mutation (SNP) | VAF 57/260 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.406); catalogued as rs753441206; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNA3 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 176/421 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63902254; called by muse, mutect2, varscan2
- KCNB2 | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 132/531 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV101578744, COSV73050926; called by muse, varscan2
- KCNG4 | c.1507G>A p.D503N | Missense Mutation (SNP) | VAF 53/226 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs145735728, COSV57584380; called by muse, varscan2
- KCNH1 | c.1816G>A p.D606N (on ENST00000271751 / NM_172362.3; = p.D579N on NM_002238.4) | Missense Mutation (SNP) | VAF 175/658 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV55087273; called by muse, mutect2, varscan2
- KCNH2 | c.2459G>A p.G820E | Missense Mutation (SNP) | VAF 173/493 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as CM139895; called by muse, mutect2, varscan2
- KCNH3 | c.2707C>G p.R903G | Missense Mutation (SNP) | VAF 139/625 reads (22%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.931); catalogued as rs148404630; called by muse, mutect2
- KCNH7 | c.2154+1G>A p.X718_splice | Splice Site (SNP) | VAF 111/557 reads (20%) | catalogued as rs747165309; called by muse, mutect2, varscan2
- KCNK18 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 119/408 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs552800446, COSV57971233; called by muse, mutect2, varscan2
- KCP | c.1111G>A p.G371R (on ENST00000620378; = p.G428R on NM_001366122.1) | Missense Mutation (SNP) | VAF 65/246 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1415007508; called by muse, mutect2, varscan2
- KCTD15 | c.35C>T p.S12L | Missense Mutation (SNP) | VAF 266/608 reads (44%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); catalogued as rs774560706, COSV99393220; called by muse, mutect2, varscan2
- KDM3B | c.4033G>A p.E1345K | Missense Mutation (SNP) | VAF 118/434 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV58689968; called by muse, mutect2, varscan2
- KIAA0513 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 62/366 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.057); catalogued as rs372567098, COSV104382912, COSV50746188; called by muse, mutect2, varscan2
- KIAA1522 | c.1559C>T p.S520L (on ENST00000373480 / NM_001198972.2; = p.S579L on NM_020888.3) | Missense Mutation (SNP) | VAF 171/660 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1247500808, COSV99614121; called by muse, mutect2, varscan2
- KIAA1549L | c.965C>T p.P322L (on ENST00000321505; = p.P619L on NM_012194.3) | Missense Mutation (SNP) | VAF 123/395 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs779946578; called by muse, mutect2, varscan2
- KIAA1755 | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 171/571 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV54077554; called by muse, mutect2, varscan2
- KIF1B | c.4628C>T p.T1543I (on ENST00000377086 / NM_001365952.1; = p.T1497I on NM_015074.3) | Missense Mutation (SNP) | VAF 133/388 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.159); catalogued as rs1327974609; called by muse, mutect2, varscan2
- KL | c.2359C>T p.P787S | Missense Mutation (SNP) | VAF 109/377 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66309952; called by muse, mutect2, varscan2
- KLK14 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 107/674 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.011); catalogued as rs367549276; called by muse, mutect2, varscan2
- KLK15 | c.316G>A p.D106N | Missense Mutation (SNP) | VAF 79/647 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1334556379, COSV56826981; called by muse, mutect2, varscan2
- KLK8 | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 44/376 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.329); catalogued as rs1332741543, COSV51594392; called by muse, mutect2, varscan2
- KLRG2 | c.952C>T p.Q318* | Nonsense Mutation (SNP) | VAF 127/495 reads (26%) | catalogued as rs201379935; called by muse, mutect2, varscan2
- KMO | c.1343G>A p.R448Q | Missense Mutation (SNP) | VAF 150/514 reads (29%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as rs1042396037, COSV59363386; called by muse, mutect2, varscan2
- KMT2B | c.6316C>T p.P2106S | Missense Mutation (SNP) | VAF 300/718 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as rs771441672; called by muse, mutect2
- KMT2C | c.2765C>T p.P922L | Missense Mutation (SNP) | VAF 47/250 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs926439234, COSV100070508; called by muse, mutect2, varscan2
- KMT2D | c.10966C>T p.R3656C | Missense Mutation (SNP) | VAF 155/608 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as rs201283589, CM146869; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- KRT12 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 214/481 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52432324; called by muse, mutect2, varscan2
- KRT33A | c.1184G>A p.R395Q | Missense Mutation (SNP) | VAF 137/637 reads (22%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.217); catalogued as rs768584703, COSV50366541; called by muse, mutect2, varscan2
- KRT33B | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 115/561 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1003555947; called by muse, mutect2, varscan2
- KRT9 | c.1348G>A p.E450K | Missense Mutation (SNP) | VAF 89/437 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55854363; called by muse, mutect2, varscan2
- KRTAP4-6 | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 256/1937 reads (13%) | SIFT deleterious (0.03); catalogued as COSV61981370; called by muse, mutect2, varscan2
- LAMA2 | c.5990G>C p.G1997A | Missense Mutation (SNP) | VAF 66/267 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.075); catalogued as COSV70350908; called by muse, mutect2, varscan2
- LGALS9C | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 72/255 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as rs1329144734, COSV60195598; called by muse, mutect2, varscan2
- LGI2 | c.1154C>T p.S385L | Missense Mutation (SNP) | VAF 153/582 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as COSV66122462; called by muse, mutect2, varscan2
- LINC00514 | c.4G>A p.G2S | Missense Mutation (SNP) | VAF 131/397 reads (33%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.934); catalogued as rs917479403; called by muse, mutect2, varscan2
- LLGL2 | c.2877G>A p.R959= | Splice Region (SNP) | VAF 86/1074 reads (8%) | catalogued as COSV51366384; called by muse, mutect2
- LMAN1 | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 80/359 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99195346; called by muse, mutect2, varscan2
- LPA | c.6026C>T p.S2009F | Missense Mutation (SNP) | VAF 117/502 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60313371; called by muse, mutect2, varscan2
- LPA | c.4216G>A p.G1406R | Missense Mutation (SNP) | VAF 111/459 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV60309424; called by muse, mutect2, varscan2
- LRP1B | c.4840G>A p.D1614N | Missense Mutation (SNP) | VAF 91/463 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as rs762458785, COSV67183175, COSV67187424; called by muse, mutect2, varscan2
- LRRC3 | c.239C>A p.P80Q | Missense Mutation (SNP) | VAF 70/405 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV52398773; called by mutect2, varscan2
- LRRC4C | c.259C>T p.Q87* | Nonsense Mutation (SNP) | VAF 62/397 reads (16%) | catalogued as COSV53419607; called by muse, mutect2, varscan2
- LY86 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 70/253 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.185); catalogued as COSV57911470; called by muse, mutect2, varscan2
- LYST | c.9980C>T p.P3327L | Missense Mutation (SNP) | VAF 106/404 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1252557907; called by muse, mutect2, varscan2
- MAGEA6 | c.899C>T p.S300F | Missense Mutation (SNP) | VAF 55/321 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as COSV61449473; called by muse, mutect2, varscan2
- MALRD1 | c.1104T>A p.N368K | Missense Mutation (SNP) | VAF 37/190 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.013); catalogued as rs1296227425; called by muse, mutect2, varscan2
- MAN2A1 | c.496C>T p.L166F | Missense Mutation (SNP) | VAF 67/384 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54847260, COSV99811657; called by muse, mutect2, varscan2
- MAP2K5 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 80/329 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs751579877; called by muse, mutect2, varscan2
- MAP2K5 | c.646C>T p.L216F | Missense Mutation (SNP) | VAF 46/169 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1333600984; called by muse, mutect2, varscan2
- MAPK12 | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 98/397 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs150223264; called by muse, mutect2, varscan2
- MAPK13 | c.1033G>C p.E345Q | Missense Mutation (SNP) | VAF 115/425 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); catalogued as COSV52982599; called by muse, mutect2, varscan2
- MAT1A | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 89/330 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1242659514, CM058289; called by muse, mutect2, varscan2
- MB21D2 | c.1432G>A p.D478N | Missense Mutation (SNP) | VAF 101/413 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs371324905; called by muse, mutect2, varscan2
- MBD3L1 | c.572C>T p.P191L | Missense Mutation (SNP) | VAF 36/289 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV59776627; called by muse, varscan2
- MBD3L3 | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 74/1184 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.01); catalogued as rs1200194303; called by muse, mutect2
- MDGA2 | c.1927T>C p.Y643H (on ENST00000399232 / NM_001113498.2; = p.Y345H on NM_182830.4) | Missense Mutation (SNP) | VAF 134/460 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.047); catalogued as COSV62095960; called by muse, mutect2, varscan2
- MDM1 | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 82/273 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as rs150886543; called by muse, mutect2, varscan2
- MDM4 | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 134/469 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as rs1405649744, COSV65795237; called by muse, mutect2, varscan2
- MECR | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 168/373 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.238); catalogued as rs1335403665, COSV55288203; called by muse, mutect2, varscan2
- MEGF6 | c.437C>G p.P146R | Missense Mutation (SNP) | VAF 154/427 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.192); catalogued as COSV62993413; called by muse, mutect2, varscan2
- MEIS2 | c.496G>A p.E166K (on ENST00000561208 / NM_170675.5; = p.E153K on NM_002399.3) | Missense Mutation (SNP) | VAF 91/215 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54932630; called by muse, mutect2, varscan2
- MEOX2 | c.530G>A p.G177E | Missense Mutation (SNP) | VAF 65/277 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.204); catalogued as rs867233014, COSV56288658; called by muse, mutect2, varscan2
- MESD | c.526G>A p.G176S | Missense Mutation (SNP) | VAF 138/536 reads (26%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as rs777525821; called by muse, mutect2, varscan2
- MGAM | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 96/348 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.109); catalogued as rs782491222; called by muse, mutect2, varscan2
- MGAM2 | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 115/368 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0.022); catalogued as rs567518439; called by muse, mutect2, varscan2
- MGAT4C | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 55/276 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.251); catalogued as rs1232939223, COSV100152742, COSV59832709; called by muse, mutect2, varscan2
- MGAT5 | c.512C>T p.P171L | Missense Mutation (SNP) | VAF 119/344 reads (35%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1191662425, COSV56097434; called by muse, mutect2, varscan2
- MGLL | c.480G>A p.K160= (on ENST00000398104 / NM_001003794.2; = p.K170= on NM_007283.6) | Splice Region (SNP) | VAF 120/408 reads (29%) | catalogued as COSV99412214; called by muse, mutect2, varscan2
- MIDEAS | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 93/556 reads (17%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.003); catalogued as rs773343786, COSV99678617; called by muse, mutect2, varscan2
- MKRN3 | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 152/599 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.908); catalogued as rs777359232, COSV58810220; called by muse, mutect2, varscan2
- MKX | c.865G>A p.G289S | Missense Mutation (SNP) | VAF 51/386 reads (13%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV65391989; called by muse, mutect2, varscan2
- MKX | c.728G>A p.G243E | Missense Mutation (SNP) | VAF 57/398 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65391852; called by muse, mutect2
- MLXIPL | c.1408T>C p.F470L | Missense Mutation (SNP) | VAF 52/292 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.347); catalogued as rs1471263426; called by mutect2, varscan2
- MMP15 | c.1285C>T p.R429C | Missense Mutation (SNP) | VAF 55/289 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as rs371785163, COSV54681146; called by muse, mutect2, varscan2
- MOB3B | c.5C>T p.S2F | Missense Mutation (SNP) | VAF 74/280 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as COSV51789988; called by muse, mutect2, varscan2
- MORC1 | c.1546C>T p.P516S | Missense Mutation (SNP) | VAF 45/282 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51730882; called by muse, mutect2, varscan2
- MROH2B | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 129/534 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV68184920; called by muse, mutect2, varscan2
- MROH9 | c.2425G>A p.A809T | Missense Mutation (SNP) | VAF 65/330 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.187); catalogued as rs935505662; called by muse, mutect2, varscan2
- MUC12 | c.7829C>T p.S2610F (on ENST00000379442; = p.S2467F on NM_001164462.1) | Missense Mutation (SNP) | VAF 110/1546 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.834); catalogued as rs1272004568; called by muse, mutect2
- MUC12 | c.11872C>T p.R3958C (on ENST00000379442; = p.R3815C on NM_001164462.1) | Missense Mutation (SNP) | VAF 161/431 reads (37%) | SIFT deleterious (0.05); catalogued as rs1341378963; called by muse, mutect2, varscan2
- MUC16 | c.42653C>T p.P14218L | Missense Mutation (SNP) | VAF 80/391 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV101109581, COSV66690346; called by muse, mutect2, varscan2
- MUC16 | c.42652C>T p.P14218S | Missense Mutation (SNP) | VAF 79/391 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.979); catalogued as rs530407564; called by muse, mutect2, varscan2
- MUC16 | c.35126C>T p.S11709F | Missense Mutation (SNP) | VAF 204/546 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.997); catalogued as rs867582847, COSV67448609; called by muse, mutect2, varscan2
- MUC16 | c.29164G>A p.E9722K | Missense Mutation (SNP) | VAF 52/473 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.031); catalogued as COSV67473438; called by muse, mutect2, varscan2
- MUC16 | c.26240C>T p.S8747F | Missense Mutation (SNP) | VAF 78/534 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.409); catalogued as rs1405483275; called by muse, mutect2, varscan2
- MUC16 | c.21026C>T p.S7009F | Missense Mutation (SNP) | VAF 205/483 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV67450400, COSV67455274; called by muse, mutect2, varscan2
- MUC16 | c.413G>A p.G138E | Missense Mutation (SNP) | VAF 191/476 reads (40%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.197); catalogued as rs769571404, COSV67446414; called by muse, mutect2, varscan2
- MUC19 | c.896G>A p.G299E | Missense Mutation (SNP) | VAF 92/330 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); catalogued as rs1190892237; called by muse, mutect2, varscan2
- MUC4 | c.11540C>T p.S3847F | Missense Mutation (SNP) | VAF 197/592 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.496); catalogued as rs1560305759, COSV100205183; called by muse, varscan2
- MUC5B | c.8270G>A p.R2757Q | Missense Mutation (SNP) | VAF 90/484 reads (19%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs548726067, COSV101500324; called by muse, mutect2, varscan2
- MYBPC3 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 55/450 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as rs1298520392; called by muse, mutect2, varscan2
- MYO10 | c.1144G>A p.G382R | Missense Mutation (SNP) | VAF 116/393 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs1165077809; called by muse, mutect2, varscan2
- MYO15A | c.1546G>A p.E516K | Missense Mutation (SNP) | VAF 183/437 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.081); catalogued as rs746673301; called by muse, mutect2, varscan2
- MYO15B | c.1258G>A p.G420R | Missense Mutation (SNP) | VAF 264/756 reads (35%) | SIFT tolerated, low confidence (0.06); catalogued as rs1172979002; called by muse, mutect2, varscan2
- MYO3A | c.4561G>A p.E1521K | Missense Mutation (SNP) | VAF 50/193 reads (26%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.551); catalogued as COSV56341733; called by muse, mutect2, varscan2
- MYO5B | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 105/410 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs762183636, COSV53214965; called by muse, mutect2, varscan2
- NAA11 | c.368C>G p.S123C | Missense Mutation (SNP) | VAF 83/549 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV54516343; called by muse, mutect2, varscan2
- NALCN | c.2729G>A p.R910Q | Missense Mutation (SNP) | VAF 116/306 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs932887695; called by muse, mutect2, varscan2
- NCAN | c.2858G>A p.W953* | Nonsense Mutation (SNP) | VAF 93/675 reads (14%) | catalogued as rs1282025326; called by muse, mutect2, varscan2
- NCKAP5 | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 63/300 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs775385683, COSV100489265, COSV58428895; called by muse, mutect2, varscan2
- NEB | c.16709C>T p.A5570V | Missense Mutation (SNP) | VAF 73/335 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50907973; called by muse, mutect2, varscan2
- NEBL | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 65/206 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV65803562; called by muse, mutect2, varscan2
- NF1 | c.3520C>T p.Q1174* | Nonsense Mutation (SNP) | VAF 160/386 reads (41%) | catalogued as rs868450405, CM001259, COSV62192372; called by muse, mutect2, varscan2
- NHLRC4 | c.301G>A p.G101S | Missense Mutation (SNP) | VAF 169/482 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.73); catalogued as rs757827816; called by muse, mutect2, varscan2
- NIM1K | c.223C>T p.R75* | Nonsense Mutation (SNP) | VAF 161/531 reads (30%) | catalogued as rs145190045; called by muse, mutect2, varscan2
- NKX2-6 | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 250/748 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.497); catalogued as rs1479779377; called by muse, mutect2, varscan2
- NLRP3 | c.1174G>A p.A392T | Missense Mutation (SNP) | VAF 132/532 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs1412367967, COSV60226917; called by muse, mutect2, varscan2
- NLRP6 | c.2207C>T p.S736F | Missense Mutation (SNP) | VAF 42/274 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.543); catalogued as rs1229059784; called by muse, mutect2, varscan2
- NOL4 | c.1445C>T p.S482F | Missense Mutation (SNP) | VAF 79/280 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV52344248; called by muse, mutect2, varscan2
- NPAS1 | c.1168G>A p.G390R | Missense Mutation (SNP) | VAF 207/556 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.865); catalogued as rs768081134; called by muse, mutect2, varscan2
- NPBWR1 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 270/763 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV58696144; called by muse, mutect2, varscan2
- NR2F6 | c.533C>T p.P178L | Missense Mutation (SNP) | VAF 90/749 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1163044697; called by muse, mutect2, varscan2
- NT5C1B | c.40G>A p.G14R | Missense Mutation (SNP) | VAF 78/375 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.898); catalogued as rs150854562; called by muse, mutect2, varscan2
- NTRK1 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 90/408 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV62323355; called by muse, mutect2, varscan2
- NUAK1 | c.1608G>A p.M536I | Missense Mutation (SNP) | VAF 124/509 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV54601489; called by muse, mutect2, varscan2
- OAS3 | c.2074C>T p.R692* | Nonsense Mutation (SNP) | VAF 77/237 reads (32%) | catalogued as rs752917599, COSV57444390; called by muse, mutect2, varscan2
- OBSCN | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 112/408 reads (27%) | SIFT tolerated (0.28); PolyPhen probably damaging (1); catalogued as rs1263435848; called by muse, mutect2, varscan2
- OGN | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 100/369 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as COSV52760999; called by muse, mutect2, varscan2
- OR10C1 | c.89C>T p.S30F (on ENST00000622521; = p.S28F on NM_013941.3) | Missense Mutation (SNP) | VAF 204/786 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as COSV65823891; called by muse, mutect2, varscan2
- OR10Q1 | c.875C>T p.P292L | Missense Mutation (SNP) | VAF 146/389 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100372209; called by muse, mutect2, varscan2
- OR11G2 | c.160G>A p.G54S | Missense Mutation (SNP) | VAF 130/452 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.725); catalogued as rs1331530755; called by muse, mutect2, varscan2
- OR14I1 | c.636G>A p.M212I | Missense Mutation (SNP) | VAF 85/325 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs755070553, COSV61199519, COSV61199705; called by muse, mutect2, varscan2
- OR1J2 | c.784C>T p.P262S | Missense Mutation (SNP) | VAF 96/386 reads (25%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.437); catalogued as COSV58945064; called by muse, mutect2, varscan2
- OR2A25 | c.751T>A p.Y251N | Missense Mutation (SNP) | VAF 119/501 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68717072; called by muse, mutect2, varscan2
- OR2G2 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 81/429 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763315277, COSV60741363; called by muse, mutect2, varscan2
- OR2M3 | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 103/398 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV71758891; called by muse, mutect2, varscan2
- OR2T2 | c.281C>T p.S94F | Missense Mutation (SNP) | VAF 196/1319 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as rs1431425376, COSV61617845; called by muse, mutect2, varscan2
- OR4C11 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 66/426 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.798); catalogued as COSV56352870; called by muse, mutect2
- OR4K13 | c.695G>A p.R232Q | Missense Mutation (SNP) | VAF 53/370 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as rs1267681977, COSV59859434; called by muse, mutect2, varscan2
- OR4M1 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 65/439 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as rs760327097, COSV60059765, COSV60060322, COSV60060528; called by muse, mutect2, varscan2
- OR4N2 | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 62/216 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100269406, COSV60050137; called by muse, mutect2, varscan2
- OR51B5 | c.79G>T p.V27L | Missense Mutation (SNP) | VAF 123/396 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV56176571; called by muse, mutect2, varscan2
- OR52B2 | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 63/414 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV73209648; called by muse, mutect2, varscan2
- OR52E5 | c.896G>A p.R299Q | Missense Mutation (SNP) | VAF 103/335 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as rs563642311; called by muse, mutect2, varscan2
- OR52E6 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 58/338 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as COSV61432640; called by muse, mutect2, varscan2
- OR5C1 | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 107/429 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs764398782; called by muse, mutect2, varscan2
- OR5D14 | c.695C>T p.S232F | Missense Mutation (SNP) | VAF 56/390 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV59455839, COSV59455992, COSV59456526; called by muse, mutect2, varscan2
- OR5D3P | c.162G>A p.M54I | Missense Mutation (SNP) | VAF 44/351 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.168); catalogued as rs1565095270; called by muse, mutect2, varscan2
- OR5H2 | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 66/435 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV62350202; called by muse, mutect2, varscan2
- OR5V1 | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 123/399 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs867652492, COSV65830848; called by muse, varscan2
- OR6A2 | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 154/479 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs1429420751; called by muse, mutect2, varscan2
- OR6B3 | c.622G>C p.V208L | Missense Mutation (SNP) | VAF 212/645 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.174); catalogued as rs776042532; called by muse, mutect2, varscan2
- OR6C2 | c.49G>A p.G17S | Missense Mutation (SNP) | VAF 124/289 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs756786518; called by muse, mutect2, varscan2
- OR6K6 | c.739C>T p.R247W (on ENST00000368144; = p.R223W on NM_001005184.1) | Missense Mutation (SNP) | VAF 121/537 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs761371256, COSV63743686, COSV63744135; called by muse, mutect2, varscan2
- OR6P1 | c.545C>T p.S182F | Missense Mutation (SNP) | VAF 82/429 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1171962857, COSV58109462; called by muse, mutect2, varscan2
- OR7C2 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 133/303 reads (44%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.097); catalogued as rs267605312, COSV99934530; called by muse, mutect2, varscan2
- OR7G3 | c.742G>A p.V248I | Missense Mutation (SNP) | VAF 210/483 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.558); catalogued as rs768063133; called by muse, mutect2, varscan2
- OR8H1 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 151/456 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.637); catalogued as rs199982658, COSV57293040; called by muse, varscan2
- OR8H1 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 154/542 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs867315106, COSV57293250; called by muse, varscan2
- OR8J1 | c.106G>T p.G36W | Missense Mutation (SNP) | VAF 80/559 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.823); catalogued as COSV57316680; called by muse, mutect2, varscan2
- OSBPL10 | c.749G>A p.G250E | Missense Mutation (SNP) | VAF 111/408 reads (27%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.978); catalogued as rs763437591; called by muse, mutect2, varscan2
- OSMR | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 90/424 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); catalogued as COSV57086922; called by muse, varscan2
- P2RX2 | c.1345G>A p.G449S (on ENST00000343948 / NM_170683.4; = p.G351S on NM_012226.5) | Missense Mutation (SNP) | VAF 199/785 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.116); catalogued as rs1160442460; called by muse, mutect2, varscan2
- PAF1 | c.890G>T p.W297L | Missense Mutation (SNP) | VAF 43/317 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV55393398; called by muse, mutect2, varscan2
- PAK5 | c.1620G>A p.M540I | Missense Mutation (SNP) | VAF 56/217 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); catalogued as COSV62037728; called by muse, mutect2, varscan2
- PARP14 | c.3599C>T p.P1200L | Missense Mutation (SNP) | VAF 95/411 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as rs745695997; called by muse, mutect2, varscan2
- PCDH12 | c.2188G>A p.G730R | Missense Mutation (SNP) | VAF 150/574 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.375); catalogued as rs755424368, COSV51518894; called by muse, mutect2
- PCDHA10 | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 88/416 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.046); catalogued as COSV56516308; called by muse, mutect2, varscan2
- PCDHA11 | c.1214C>T p.S405L | Missense Mutation (SNP) | VAF 148/568 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs782216904, COSV56539171; called by muse, mutect2, varscan2
- PCDHA13 | c.1295C>T p.S432L | Missense Mutation (SNP) | VAF 220/766 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.224); catalogued as COSV56491140; called by muse, mutect2, varscan2
- PCDHA8 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 179/757 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV65337144; called by muse, mutect2, varscan2
- PCDHA8 | c.1528G>A p.V510M | Missense Mutation (SNP) | VAF 245/960 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65332072; called by muse, mutect2, varscan2
- PCDHB10 | c.1315G>T p.V439F | Missense Mutation (SNP) | VAF 179/677 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.853); catalogued as COSV99504304; called by muse, mutect2, varscan2
- PCDHB11 | c.1127G>A p.G376E | Missense Mutation (SNP) | VAF 110/456 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.908); catalogued as COSV61314175; called by muse, mutect2, varscan2
- PCDHB14 | c.29G>A p.R10Q | Missense Mutation (SNP) | VAF 42/480 reads (9%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.003); catalogued as rs782260168, COSV53386710, COSV99505501; called by muse, mutect2
- PCDHB3 | c.2254G>A p.E752K | Missense Mutation (SNP) | VAF 91/370 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.169); catalogued as rs267600412, COSV50581081; called by muse, mutect2, varscan2
- PCDHB6 | c.1897G>A p.A633T | Missense Mutation (SNP) | VAF 222/856 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); catalogued as rs781983350, COSV99173251; called by muse, mutect2, varscan2
- PCDHB9 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 156/610 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.047); catalogued as COSV53378882; called by muse, mutect2, varscan2
- PCDHGA11 | c.848G>A p.R283Q | Missense Mutation (SNP) | VAF 90/352 reads (26%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.066); catalogued as rs1192481253; called by muse, mutect2, varscan2
- PCDHGA12 | c.839C>T p.S280F | Missense Mutation (SNP) | VAF 120/483 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.072); catalogued as rs999687684, COSV52749440; called by muse, mutect2, varscan2
- PCIF1 | c.970C>T p.R324W | Missense Mutation (SNP) | VAF 129/454 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1228976852; called by muse, mutect2, varscan2
- PCLO | c.8185G>A p.D2729N | Missense Mutation (SNP) | VAF 97/374 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100437547; called by muse, mutect2, varscan2
- PCLO | c.4651G>A p.E1551K | Missense Mutation (SNP) | VAF 100/398 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.298); catalogued as rs1390343890, COSV61632542; called by muse, mutect2, varscan2
- PCLO | c.2945C>T p.S982F | Missense Mutation (SNP) | VAF 54/432 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.116); catalogued as COSV61661666; called by muse, mutect2, varscan2
- PCLO | c.931C>T p.P311S | Missense Mutation (SNP) | VAF 87/603 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.006); catalogued as COSV61636478; called by muse, mutect2, varscan2
- PCNX2 | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 116/429 reads (27%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs766643762; called by muse, mutect2, varscan2
- PDE3B | c.2510A>T p.N837I | Missense Mutation (SNP) | VAF 32/238 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV99962472; called by muse, mutect2, varscan2
- PDLIM7 | c.1123C>T p.R375W | Missense Mutation (SNP) | VAF 119/531 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs147300820, COSV63080319, COSV63081888; called by muse, mutect2, varscan2
- PDYN | c.299G>A p.G100E | Missense Mutation (SNP) | VAF 163/553 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.059); catalogued as COSV54101663, COSV99452612; called by muse, mutect2, varscan2
- PDZD2 | c.3181G>A p.D1061N | Missense Mutation (SNP) | VAF 120/479 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.029); catalogued as COSV56875878; called by muse, mutect2, varscan2
- PEX6 | c.50C>T p.P17L | Missense Mutation (SNP) | VAF 160/596 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1412728890, COSV55103846; called by muse, mutect2, varscan2
- PGD | c.1283C>T p.S428F | Missense Mutation (SNP) | VAF 77/229 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs562944056, COSV54620971; called by muse, mutect2, varscan2
- PGK2 | c.932G>A p.W311* | Nonsense Mutation (SNP) | VAF 126/495 reads (25%) | catalogued as COSV100505576; called by muse, mutect2, varscan2
- PHC3 | c.790C>T p.P264S (on ENST00000494943 / NM_001308116.2; = p.P276S on NM_024947.4) | Missense Mutation (SNP) | VAF 116/436 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.14); catalogued as rs1306196130, COSV101520179; called by muse, mutect2, varscan2
- PHF21B | c.1115G>A p.G372E | Missense Mutation (SNP) | VAF 177/718 reads (25%) | SIFT tolerated (1); PolyPhen possibly damaging (0.446); catalogued as COSV100504005; called by muse, mutect2, varscan2
- PIEZO2 | c.7637C>T p.S2546L | Missense Mutation (SNP) | VAF 43/200 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as rs371283340; called by muse, mutect2, varscan2
- PIK3C2G | c.3064C>T p.R1022C (on ENST00000676171; = p.R981C on NM_004570.5) | Missense Mutation (SNP) | VAF 101/401 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.899); catalogued as rs774333984, COSV56819263; called by muse, mutect2, varscan2
- PKHD1 | c.8936G>A p.R2979Q | Missense Mutation (SNP) | VAF 34/322 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.141); catalogued as rs761651295, COSV100581179; called by muse, mutect2, varscan2
- PKHD1L1 | c.8590C>T p.L2864F | Missense Mutation (SNP) | VAF 70/333 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.313); catalogued as COSV65754664; called by muse, mutect2, varscan2
- PKP2 | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 173/534 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as COSV99297362; called by muse, mutect2, varscan2
- PLA2R1 | c.3158C>T p.P1053L | Missense Mutation (SNP) | VAF 65/240 reads (27%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.598); catalogued as rs764205342, COSV99323442; called by muse, mutect2, varscan2
- PLCG1 | c.637T>C p.F213L | Missense Mutation (SNP) | VAF 104/399 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as rs778157478; called by muse, mutect2, varscan2
- PLCL1 | c.2678C>T p.P893L | Missense Mutation (SNP) | VAF 107/365 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.118); catalogued as rs755068243, COSV70840063; called by muse, mutect2, varscan2
- PLG | c.50G>A p.G17D | Missense Mutation (SNP) | VAF 92/295 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.758); catalogued as rs755657852; called by muse, mutect2, varscan2
- PLIN1 | c.1316C>T p.P439L | Missense Mutation (SNP) | VAF 140/542 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs572633629; called by muse, mutect2, varscan2
- PLXDC2 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 34/229 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as COSV65904260; called by muse, mutect2, varscan2
- PLXND1 | c.3476C>T p.P1159L | Missense Mutation (SNP) | VAF 168/721 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV60719028; called by muse, mutect2, varscan2
- PNLIP | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 80/246 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as rs1399292461; called by muse, mutect2, varscan2
- POF1B | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 105/315 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs146172066, COSV99427068; called by muse, mutect2, varscan2
- PPP1R2B | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 120/523 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.124); catalogued as rs771781281, COSV70373112; called by muse, mutect2, varscan2
- PRAMEF19 | c.703C>T p.R235* | Nonsense Mutation (SNP) | VAF 96/245 reads (39%) | catalogued as rs1388603521; called by muse, mutect2, varscan2
- PRB2 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 208/739 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV101231392; called by muse, mutect2, varscan2
- PRB2 | c.44C>T p.S15L | Missense Mutation (SNP) | VAF 46/325 reads (14%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.387); catalogued as rs1477662042, COSV66983924; called by muse, mutect2, varscan2
- PRDM10 | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 127/291 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs898114731; called by muse, mutect2, varscan2
- PRDM2 | c.1723C>T p.Q575* | Nonsense Mutation (SNP) | VAF 100/232 reads (43%) | catalogued as rs867608891; called by muse, mutect2, varscan2
- PRDM9 | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 231/758 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); catalogued as COSV57013427; called by muse, mutect2, varscan2
- PROM1 | c.2195C>T p.S732F | Missense Mutation (SNP) | VAF 97/337 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs750175937; called by muse, mutect2, varscan2
- PRR5L | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 121/336 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs751977077, COSV61122304; called by muse, mutect2, varscan2
- PRRC2B | c.784C>T p.R262* | Nonsense Mutation (SNP) | VAF 108/436 reads (25%) | catalogued as COSV61942555; called by muse, mutect2, varscan2
- PRRG3 | c.180G>A p.W60* | Nonsense Mutation (SNP) | VAF 97/260 reads (37%) | catalogued as COSV100948690; called by muse, mutect2, varscan2
- PRSS16 | c.1370C>T p.A457V | Missense Mutation (SNP) | VAF 106/400 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.086); catalogued as COSV100042031; called by muse, mutect2, varscan2
- PRUNE2 | c.3995G>A p.G1332E | Missense Mutation (SNP) | VAF 166/557 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV65038656; called by muse, mutect2, varscan2
- PRX | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 84/711 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as rs1314803864; called by muse, mutect2, varscan2
- PSG7 | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 29/305 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV68446426; called by muse, mutect2
- PSG8 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 72/482 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV60615880; called by muse, varscan2
- PSG9 | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 54/461 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.901); catalogued as rs751794957, COSV99392006, COSV99392019; called by muse, mutect2, varscan2
- PSPC1 | c.1522G>A p.G508R | Missense Mutation (SNP) | VAF 70/594 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763295856; called by muse, mutect2
- PTPN12 | c.352T>C p.W118R | Missense Mutation (SNP) | VAF 77/307 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50354100; called by muse, mutect2, varscan2
- PTPN13 | c.5246C>T p.S1749L (on ENST00000411767 / NM_080683.3; = p.S1730L on NM_006264.3) | Missense Mutation (SNP) | VAF 143/484 reads (30%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs724159902, COSV57404496; called by muse, mutect2, varscan2
- PTPRD | c.3994G>A p.A1332T | Missense Mutation (SNP) | VAF 64/277 reads (23%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as COSV100645953, COSV61927267; called by muse, mutect2, varscan2
- PTPRD | c.2377G>A p.E793K | Missense Mutation (SNP) | VAF 87/357 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.142); catalogued as COSV61971815; called by muse, mutect2, varscan2
- PTPRH | c.580G>A p.G194R | Missense Mutation (SNP) | VAF 65/501 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.515); catalogued as COSV54750903; called by muse, mutect2, varscan2
- PTPRR | c.773C>T p.S258F | Missense Mutation (SNP) | VAF 101/360 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs200473700; called by muse, mutect2, varscan2
- PTPRU | c.1697C>T p.S566F | Missense Mutation (SNP) | VAF 314/678 reads (46%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV60521907; called by muse, mutect2, varscan2
- PTTG2 | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 104/375 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV54729670; called by muse, mutect2, varscan2
- PXDNL | c.2195G>A p.G732D | Missense Mutation (SNP) | VAF 292/801 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100683083; called by muse, mutect2, varscan2
- PZP | c.2057C>T p.S686L | Missense Mutation (SNP) | VAF 42/402 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs868640101, COSV54361212; called by muse, mutect2, varscan2
- RANBP3 | c.1472C>T p.S491L (on ENST00000340578 / NM_007322.3; = p.S486L on NM_003624.3) | Missense Mutation (SNP) | VAF 113/267 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1161820034; called by muse, mutect2, varscan2
- RBFOX1 | c.682G>A p.V228I | Missense Mutation (SNP) | VAF 114/378 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs370824348; called by muse, varscan2
- RBL2 | c.1393G>A p.E465K | Missense Mutation (SNP) | VAF 105/330 reads (32%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.829); catalogued as COSV50873231; called by muse, mutect2, varscan2
- RBPJL | c.1480G>A p.D494N | Missense Mutation (SNP) | VAF 195/693 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1375702228, COSV59213690; called by muse, mutect2, varscan2
- RCN2 | c.554A>G p.Y185C | Missense Mutation (SNP) | VAF 62/299 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs147190935; called by muse, mutect2, varscan2
- REG3G | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 71/458 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs1037519345, COSV55448569, COSV55449491; called by muse, mutect2, varscan2
- RESP18 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 46/303 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.728); catalogued as rs367654700; called by muse, mutect2, varscan2
- RFPL4AL1 | c.84T>A p.Y28* | Nonsense Mutation (SNP) | VAF 52/715 reads (7%) | catalogued as COSV59112248; called by muse, mutect2
- RFPL4B | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 157/607 reads (26%) | SIFT tolerated (0.76); PolyPhen probably damaging (0.986); catalogued as rs760736784, COSV71437245; called by muse, mutect2, varscan2
- RFX3 | c.1528C>T p.R510C | Missense Mutation (SNP) | VAF 115/479 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56524622; called by muse, mutect2, varscan2
- RGPD4 | c.4495G>A p.E1499K | Missense Mutation (SNP) | VAF 45/453 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.288); catalogued as rs772988973; called by muse, mutect2, varscan2
- RGS22 | c.2224G>A p.E742K | Missense Mutation (SNP) | VAF 103/462 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.031); catalogued as rs1286552386, COSV62664162; called by muse, mutect2, varscan2
- RGSL1 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 108/411 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs201415463, COSV54257935; called by muse, mutect2, varscan2
- RIMS2 | c.4252G>A p.D1418N (on ENST00000666250 / NM_001348490.2; = p.D989N on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 195/518 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51721268; called by muse, mutect2, varscan2
- ROS1 | c.4581G>A p.M1527I | Missense Mutation (SNP) | VAF 69/293 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV63853324; called by muse, mutect2, varscan2
- RP1 | c.1446del p.Q482Hfs*50 | Frame Shift Del (DEL) | VAF 94/444 reads (21%) | catalogued as COSV55111479; called by mutect2, varscan2
- RP1 | c.1450del p.S484Hfs*48 | Frame Shift Del (DEL) | VAF 106/620 reads (17%) | catalogued as COSV55110536; called by mutect2*, pindel, varscan2*
- RP1 | c.3844C>T p.P1282S | Missense Mutation (SNP) | VAF 118/542 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as rs866399055, COSV55111239; called by muse, mutect2, varscan2
- RP1 | c.4864G>A p.E1622K | Missense Mutation (SNP) | VAF 118/547 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.417); catalogued as rs1366220475, COSV55111333; called by muse, mutect2, varscan2
- RPGRIP1L | c.2657C>T p.S886L | Missense Mutation (SNP) | VAF 76/212 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.857); catalogued as rs762304207, COSV50904042; called by muse, mutect2, varscan2
- RUSC2 | c.1687C>T p.R563C | Missense Mutation (SNP) | VAF 156/585 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as rs761344885, COSV63428349; called by muse, mutect2, varscan2
- RYR2 | c.4387C>T p.R1463C | Missense Mutation (SNP) | VAF 120/387 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as rs764144130, COSV63712199; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SALL1 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 60/434 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV51754140; called by muse, mutect2, varscan2
- SAMD3 | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 91/297 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs201988282, COSV100931800, COSV63712931; called by muse, mutect2, varscan2
- SAMD9L | c.4606G>A p.V1536I | Missense Mutation (SNP) | VAF 93/355 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV59085688; called by muse, mutect2, varscan2
- SAV1 | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 50/304 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV61206093; called by muse, mutect2, varscan2
- SCGB1C1 | c.110T>C p.L37P | Missense Mutation (SNP) | VAF 121/654 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773252089; called by muse, mutect2, varscan2
- SCN1A | c.1747G>A p.D583N | Missense Mutation (SNP) | VAF 112/551 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as COSV57670704; called by muse, mutect2, varscan2
- SCN5A | c.2371C>T p.L791F | Missense Mutation (SNP) | VAF 156/576 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as rs1559758696; called by muse, mutect2, varscan2
- SELE | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 87/386 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV60976471; called by muse, mutect2, varscan2
- SEMG2 | c.1124C>T p.S375L | Missense Mutation (SNP) | VAF 127/498 reads (26%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.926); catalogued as rs146527428; called by muse, mutect2, varscan2
- SENP1 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 45/339 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as rs553082909, COSV50286820; called by muse, mutect2, varscan2
- SERPINB3 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 48/205 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.217); catalogued as COSV52191055; called by muse, mutect2, varscan2
- SERPINB9 | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 126/505 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0.006); catalogued as rs764353184, COSV66233095; called by muse, mutect2, varscan2
- SERPINI1 | c.662G>A p.G221E | Missense Mutation (SNP) | VAF 80/287 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as rs866041653, COSV55512904; called by muse, mutect2, varscan2
- SEZ6L | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 146/487 reads (30%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.003); catalogued as COSV50673927; called by muse, mutect2, varscan2
- SEZ6L2 | c.1444C>T p.R482C (on ENST00000308713 / NM_001114099.3; = p.R412C on NM_012410.4) | Missense Mutation (SNP) | VAF 87/505 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.594); catalogued as rs1466762799, COSV58096772; called by muse, mutect2, varscan2
- SGCG | c.259T>G p.L87V | Missense Mutation (SNP) | VAF 98/333 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54562047, COSV99523267; called by muse, mutect2, varscan2
- SH3GL3 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 115/441 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as rs149232982; called by muse, varscan2
- SHBG | c.226C>T p.R76* | Nonsense Mutation (SNP) | VAF 74/225 reads (33%) | catalogued as rs745807575, COSV52646360; called by muse, mutect2, varscan2
- SHROOM3 | c.2633C>T p.P878L | Missense Mutation (SNP) | VAF 204/685 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as rs762287204, COSV56039077; called by muse, mutect2, varscan2
- SI | c.719G>A p.G240D | Missense Mutation (SNP) | VAF 53/450 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs763991344; called by muse, mutect2
- SIK3 | c.2374C>T p.P792S (on ENST00000445177 / NM_001366686.2; = p.P750S on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 232/464 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1014173834, COSV52615073, COSV52623976; called by muse, mutect2, varscan2
- SIRPB2 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 130/439 reads (30%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.996); catalogued as COSV63124412; called by muse, mutect2, varscan2
- SLC22A8 | c.1226C>T p.T409I | Missense Mutation (SNP) | VAF 76/288 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.02); catalogued as rs267603084, COSV100267790; called by muse, varscan2
- SLC24A3 | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 109/413 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.988); catalogued as rs1317802795, COSV60130170; called by muse, mutect2, varscan2
- SLC25A52 | c.580G>A p.G194R (on ENST00000672005; = p.G184R on NM_001034172.4) | Missense Mutation (SNP) | VAF 131/510 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as rs1324638323, COSV52504299; called by muse, mutect2, varscan2
- SLC28A1 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 149/474 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.058); catalogued as rs201974180; called by muse, mutect2, varscan2
- SLC35B1 | c.352C>T p.R118C (on ENST00000649906; = p.R81C on NM_005827.4) | Missense Mutation (SNP) | VAF 152/368 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as rs373638982; called by muse, mutect2, varscan2
- SLC4A8 | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 67/331 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60650252; called by muse, mutect2, varscan2
- SLC7A13 | c.929C>T p.S310L | Missense Mutation (SNP) | VAF 108/375 reads (29%) | SIFT tolerated (0.76); PolyPhen benign (0.025); catalogued as COSV52534550; called by muse, mutect2, varscan2
- SLC8A3 | c.2164G>A p.E722K (on ENST00000381269 / NM_183002.3; = p.E720K on NM_033262.4) | Missense Mutation (SNP) | VAF 56/398 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.977); catalogued as rs780062241, COSV99385871; called by muse, mutect2, varscan2
- SLFN13 | c.1310G>A p.G437E | Missense Mutation (SNP) | VAF 315/714 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53192773; called by muse, mutect2, varscan2
- SMTNL2 | c.931G>A p.E311K (on ENST00000389313 / NM_001114974.2; = p.E167K on NM_198501.3) | Missense Mutation (SNP) | VAF 163/428 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV58810224; called by muse, mutect2, varscan2
- SNAPC4 | c.2774C>T p.S925L | Missense Mutation (SNP) | VAF 144/527 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.446); catalogued as rs377460643; called by muse, mutect2, varscan2
- SNCAIP | c.239C>T p.S80L | Missense Mutation (SNP) | VAF 105/476 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs766577479, COSV54401099; called by muse, mutect2, varscan2
- SORBS2 | c.1897G>A p.E633K | Missense Mutation (SNP) | VAF 212/764 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs756851819, COSV52996162; called by muse, varscan2
- SORL1 | c.2710C>T p.R904W | Missense Mutation (SNP) | VAF 72/406 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148966249; called by muse, mutect2, varscan2
- SORL1 | c.3676G>A p.D1226N | Missense Mutation (SNP) | VAF 54/376 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99493699; called by muse, mutect2, varscan2
- SPAG17 | c.1423G>A p.G475R | Missense Mutation (SNP) | VAF 177/396 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1236231461, COSV100308032; called by muse, mutect2, varscan2
- SPANXD | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 99/311 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.179); catalogued as COSV65152645; called by muse, mutect2, varscan2
- SPARCL1 | c.791G>A p.G264D | Missense Mutation (SNP) | VAF 129/466 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as rs773358673; called by muse, mutect2, varscan2
- SPAST | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 130/596 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.108); catalogued as rs1471679928; called by muse, mutect2, varscan2
- SPATA20 | c.1160C>T p.S387L (on ENST00000356488 / NM_001258372.1; = p.S403L on NM_022827.4) | Missense Mutation (SNP) | VAF 121/636 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755188329; called by muse, mutect2
- SPATA31E1 | c.1286G>A p.G429E | Missense Mutation (SNP) | VAF 94/622 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.155); catalogued as rs753359007; called by muse, mutect2, varscan2
- SPEG | c.527C>T p.S176F | Missense Mutation (SNP) | VAF 207/644 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV56678077; called by muse, mutect2, varscan2
- SPHKAP | c.1332G>A p.W444* | Nonsense Mutation (SNP) | VAF 73/480 reads (15%) | catalogued as rs867872641, COSV100764162; called by muse, mutect2, varscan2
- SPRR3 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 157/526 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.871); catalogued as COSV54878722; called by muse, mutect2, varscan2
- SPTA1 | c.7045G>A p.E2349K | Missense Mutation (SNP) | VAF 102/465 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100934612; called by muse, mutect2, varscan2
- SPTA1 | c.2927T>C p.V976A | Missense Mutation (SNP) | VAF 79/365 reads (22%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as rs764659645, COSV63754432; called by muse, mutect2, varscan2
- SQOR | c.910C>T p.L304F | Missense Mutation (SNP) | VAF 102/416 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as rs772724020; called by muse, mutect2, varscan2
- SRCAP | c.4123C>T p.L1375F | Missense Mutation (SNP) | VAF 90/415 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.896); catalogued as COSV52668734; called by muse, mutect2, varscan2
- SRCIN1 | c.2683G>A p.E895K (on ENST00000621492; = p.E861K on NM_025248.3) | Missense Mutation (SNP) | VAF 50/656 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as rs780941487; called by muse, mutect2
- SRGAP3 | c.125G>A p.R42Q | Missense Mutation (SNP) | VAF 99/368 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs1466873887, COSV64531448; called by muse, mutect2, varscan2
- SSC5D | c.2021G>A p.R674Q | Missense Mutation (SNP) | VAF 250/575 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as rs373900903, COSV101046765; called by muse, mutect2, varscan2
- SSU72P4 | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 78/878 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.102); catalogued as rs1454552516; called by muse, mutect2
- STAB1 | c.6701G>A p.G2234E | Missense Mutation (SNP) | VAF 127/538 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs1348465716; called by muse, mutect2, varscan2
- STAU1 | c.941C>T p.P314L (on ENST00000371856 / NM_001319135.1; = p.P233L on NM_004602.3) | Missense Mutation (SNP) | VAF 107/426 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); catalogued as rs200245504, COSV100574507, COSV61459993; called by muse, mutect2, varscan2
- STAU2 | c.1600G>A p.E534K | Missense Mutation (SNP) | VAF 109/347 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.017); catalogued as rs1456539613; called by muse, mutect2, varscan2
- STK25 | c.131A>T p.E44V | Missense Mutation (SNP) | VAF 91/459 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.377); catalogued as rs756826952; called by muse, mutect2, varscan2
- STK33 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 61/172 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as COSV59397572; called by muse, mutect2, varscan2
- STXBP5L | c.896G>A p.G299E | Missense Mutation (SNP) | VAF 39/177 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56541763; called by muse, mutect2, varscan2
- STXBP5L | c.2087G>A p.R696Q | Missense Mutation (SNP) | VAF 71/291 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs561846083, COSV56522382; called by muse, mutect2, varscan2
- SV2B | c.223C>T p.R75W | Missense Mutation (SNP) | VAF 160/627 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs201612018, COSV57701832; called by muse, mutect2, varscan2
- SVEP1 | c.7681C>T p.P2561S | Missense Mutation (SNP) | VAF 104/419 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.93); catalogued as rs1450085654; called by muse, mutect2, varscan2
- SYNE1 | c.5455G>A p.E1819K (on ENST00000367255 / NM_182961.4; = p.E1826K on NM_033071.3) | Missense Mutation (SNP) | VAF 119/456 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.083); catalogued as rs868091637, COSV55045863; called by muse, mutect2, varscan2
- SYT16 | c.284A>G p.N95S | Missense Mutation (SNP) | VAF 61/474 reads (13%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.005); catalogued as rs745937291; called by muse, mutect2, varscan2
- TAAR2 | c.109G>T p.E37* | Nonsense Mutation (SNP) | VAF 98/421 reads (23%) | catalogued as COSV51579738; called by muse, mutect2, varscan2
- TAB2 | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 155/556 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.166); catalogued as rs1385042969; called by muse, mutect2, varscan2
- TACC2 | c.4844C>T p.P1615L | Missense Mutation (SNP) | VAF 142/469 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs1482522779; called by muse, mutect2, varscan2
- TACR1 | c.189G>A p.M63I | Missense Mutation (SNP) | VAF 97/488 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100537814, COSV59481631; called by muse, mutect2, varscan2
- TAL1 | c.809G>A p.G270E | Missense Mutation (SNP) | VAF 96/416 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV53746711, COSV99595823; called by muse, mutect2
- TARS3 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 65/239 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as rs1009609339, COSV100254436; called by muse, mutect2, varscan2
- TAS1R2 | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 78/202 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.436); catalogued as COSV100946406, COSV64747895; called by muse, mutect2, varscan2
- TAS2R9 | c.932T>G p.V311G | Missense Mutation (SNP) | VAF 74/263 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV53689221; called by muse, varscan2
- TAS2R9 | c.721C>T p.L241F | Missense Mutation (SNP) | VAF 152/624 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs1390071073; called by muse, varscan2
- TATDN2 | c.1412C>T p.P471L | Missense Mutation (SNP) | VAF 142/481 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs776999048, COSV99813627; called by muse, mutect2, varscan2
- TBC1D17 | c.385A>G p.I129V | Missense Mutation (SNP) | VAF 104/681 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.73); catalogued as rs977962869; called by muse, mutect2, varscan2
- TBCEL | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 136/275 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as COSV99412247; called by muse, mutect2, varscan2
- TBX21 | c.1198C>T p.R400* | Nonsense Mutation (SNP) | VAF 171/817 reads (21%) | catalogued as rs965811401, COSV51595325; called by muse, mutect2, varscan2
- TBX21 | c.1538C>T p.S513F | Missense Mutation (SNP) | VAF 74/674 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as COSV51595801; called by muse, mutect2, varscan2
- TBXT | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 109/432 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as rs368969464; called by muse, mutect2, varscan2
- TCP10L2 | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 128/674 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV52084246; called by muse, mutect2, varscan2
- TCP11L2 | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 80/383 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); catalogued as rs772592153, COSV54431314; called by muse, mutect2, varscan2
- TDRD15 | c.1057C>T p.P353S | Missense Mutation (SNP) | VAF 67/296 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as rs1181559910; called by muse, mutect2, varscan2
- TENT5D | c.34G>A p.D12N | Missense Mutation (SNP) | VAF 86/223 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV57638879; called by muse, mutect2, varscan2
- TEP1 | c.7298C>T p.P2433L | Missense Mutation (SNP) | VAF 55/375 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs762480078; called by muse, mutect2, varscan2
- TFPI | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 67/397 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1306063066, COSV51900026; called by muse, mutect2, varscan2
- TG | c.4367G>A p.G1456E | Missense Mutation (SNP) | VAF 91/365 reads (25%) | SIFT tolerated (0.7); PolyPhen benign (0.01); catalogued as COSV55078066; called by muse, mutect2, varscan2
- TG | c.7045G>A p.E2349K | Missense Mutation (SNP) | VAF 105/528 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.601); catalogued as rs1014647249; called by muse, mutect2, varscan2
- TGFB2 | c.899A>T p.K300M | Missense Mutation (SNP) | VAF 77/430 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV100860129; called by muse, mutect2, varscan2
- TGM6 | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 177/624 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.428); catalogued as COSV52477270; called by muse, mutect2, varscan2
- THADA | c.1378T>G p.C460G | Missense Mutation (SNP) | VAF 123/455 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs544356267; called by muse, mutect2, varscan2
- THSD7B | c.2755G>A p.E919K | Missense Mutation (SNP) | VAF 165/435 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as COSV55665774; called by muse, mutect2, varscan2
- THSD7B | c.4634G>A p.W1545* (on ENST00000272643; = p.W1543* on NM_001316349.2) | Nonsense Mutation (SNP) | VAF 77/236 reads (33%) | catalogued as COSV55742328; called by muse, mutect2, varscan2
- TIGD4 | c.1493C>T p.S498F | Missense Mutation (SNP) | VAF 71/269 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.483); catalogued as COSV58548975, COSV58549155; called by muse, mutect2, varscan2
- TLR2 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 107/427 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV52605167; called by muse, mutect2, varscan2
- TLR2 | c.2167C>T p.R723C | Missense Mutation (SNP) | VAF 128/488 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371652530; called by muse, mutect2, varscan2
- TLR4 | c.331G>A p.G111R (on ENST00000355622 / NM_138554.5; = p.G71R on NM_003266.4) | Missense Mutation (SNP) | VAF 123/520 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100790612, COSV100790618; called by muse, mutect2, varscan2
- TMC7 | c.2008C>T p.P670S | Missense Mutation (SNP) | VAF 87/276 reads (32%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.831); catalogued as COSV58587700; called by muse, mutect2, varscan2
- TMEM132A | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 176/583 reads (30%) | SIFT tolerated (0.67); PolyPhen benign (0.365); catalogued as COSV50006714; called by muse, mutect2, varscan2
- TMEM147 | c.8T>G p.L3R | Missense Mutation (SNP) | VAF 44/350 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138602496; called by muse, mutect2, varscan2
- TMPRSS11D | c.1136G>A p.R379Q | Missense Mutation (SNP) | VAF 134/476 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.04); catalogued as rs752345853; called by muse, mutect2, varscan2
- TMPRSS3 | c.380C>T p.T127I | Missense Mutation (SNP) | VAF 64/378 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as rs1453222150; called by muse, mutect2, varscan2
- TNFAIP8 | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 83/335 reads (25%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.889); catalogued as COSV57227992; called by muse, mutect2, varscan2
- TNK2 | c.274C>T p.H92Y | Missense Mutation (SNP) | VAF 154/602 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs1400733406; called by muse, mutect2, varscan2
- TNN | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 123/563 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.029); catalogued as rs755253081; called by muse, mutect2, varscan2
- TNPO1 | c.682C>T p.L228F | Missense Mutation (SNP) | VAF 91/234 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV61524236; called by muse, mutect2, varscan2
- TNRC6C | c.1808C>T p.S603L | Missense Mutation (SNP) | VAF 61/578 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as rs749997078; called by muse, mutect2, varscan2
- TRAF3IP3 | c.791G>A p.G264E | Missense Mutation (SNP) | VAF 82/302 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as rs748858980; called by muse, mutect2, varscan2
- TRAV16 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 61/348 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs755980589; called by muse, mutect2, varscan2
- TREM1 | c.295C>T p.R99* | Nonsense Mutation (SNP) | VAF 96/414 reads (23%) | catalogued as rs367952779; called by muse, mutect2, varscan2
- TRHR | c.950C>G p.P317R | Missense Mutation (SNP) | VAF 200/523 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100304588, COSV61235018; called by muse, mutect2, varscan2
- TRIML2 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 73/240 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.584); catalogued as COSV58718093; called by muse, varscan2
- TRPC7 | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 169/524 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as rs1440978507, COSV61453072; called by muse, mutect2, varscan2
- TRPM6 | c.5488G>A p.E1830K | Missense Mutation (SNP) | VAF 76/317 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62503871; called by muse, mutect2, varscan2
- TSHZ3 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 74/497 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.039); catalogued as COSV99552771; called by muse, mutect2, varscan2
- TSNAXIP1 | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 124/369 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as rs761157513, COSV66314667; called by muse, mutect2, varscan2
- TTN | c.97891G>A p.G32631S (on ENST00000591111; = p.G25207S on NM_003319.4) | Missense Mutation (SNP) | VAF 97/408 reads (24%) | PolyPhen probably damaging (0.933); catalogued as rs794729562; called by muse, mutect2, varscan2
- TTN | c.64955G>A p.G21652E (on ENST00000591111; = p.G14228E on NM_003319.4) | Missense Mutation (SNP) | VAF 159/500 reads (32%) | PolyPhen benign (0.015); catalogued as rs868610314; called by muse, mutect2, varscan2
- TTN | c.38611G>A p.E12871K (on ENST00000591111; = p.E5447K on NM_003319.4) | Missense Mutation (SNP) | VAF 153/519 reads (29%) | PolyPhen probably damaging (0.994); catalogued as COSV60078228; called by muse, mutect2, varscan2
- TTN | c.30790G>A p.E10264K (on ENST00000591111; = p.E9337K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 152/420 reads (36%) | PolyPhen benign (0.001); catalogued as COSV60070172, COSV60391857; called by muse, mutect2, varscan2
- TTN | c.26746G>A p.E8916K (on ENST00000591111; = p.E7989K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 216/534 reads (40%) | PolyPhen possibly damaging (0.54); catalogued as COSV59918127; called by muse, mutect2, varscan2
- TTN | c.23398G>A p.E7800K (on ENST00000591111; = p.E6873K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 118/636 reads (19%) | PolyPhen probably damaging (0.994); catalogued as COSV60211737; called by muse, mutect2, varscan2
- TUSC1 | c.64G>A p.G22S | Missense Mutation (SNP) | VAF 180/630 reads (29%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.059); catalogued as rs907196262; called by muse, varscan2
- TYMP | c.578C>T p.P193L | Missense Mutation (SNP) | VAF 118/430 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs865961520; called by muse, varscan2
- TYMP | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 118/428 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1236277429, COSV52687959; called by muse, varscan2
- UBE2Q1 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 61/374 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV52724737; called by muse, mutect2, varscan2
- UBQLN3 | c.699G>A p.M233I | Missense Mutation (SNP) | VAF 72/450 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.168); catalogued as COSV99061947; called by muse, mutect2, varscan2
- UGT2A3 | c.1174C>T p.P392S | Missense Mutation (SNP) | VAF 151/577 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV52359727, COSV99280126; called by muse, mutect2, varscan2
- UMAD1 | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 197/624 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.81); catalogued as rs751380851; called by muse, mutect2, varscan2
- UNC79 | c.4381G>A p.E1461K (on ENST00000393151 / NM_001346218.2; = p.E1284K on NM_020818.5) | Missense Mutation (SNP) | VAF 63/213 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.84); catalogued as rs1266608031, COSV56400039; called by muse, varscan2
- USH1C | c.1198C>T p.R400C | Missense Mutation (SNP) | VAF 44/280 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.353); catalogued as rs759009035, COSV99139193; called by muse, mutect2, varscan2
- USP29 | c.2455C>T p.P819S | Missense Mutation (SNP) | VAF 68/656 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.258); catalogued as COSV54140021; called by muse, mutect2, varscan2
- USP7 | c.1145G>A p.G382E | Missense Mutation (SNP) | VAF 52/380 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100784060; called by muse, mutect2, varscan2
- VARS1 | c.1492C>T p.R498C | Missense Mutation (SNP) | VAF 187/658 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as rs766191219; called by muse, mutect2, varscan2
- VARS1 | c.1201G>A p.G401R | Missense Mutation (SNP) | VAF 215/801 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.168); catalogued as rs768532513; called by muse, mutect2, varscan2
- VAV2 | c.1679G>A p.G560E (on ENST00000371850 / NM_001134398.2; = p.G550E on NM_003371.4) | Missense Mutation (SNP) | VAF 60/445 reads (13%) | SIFT tolerated (0.23); PolyPhen probably damaging (1); catalogued as rs754695036; called by muse, mutect2
- VIPR2 | c.854G>A p.R285Q | Missense Mutation (SNP) | VAF 111/366 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.892); catalogued as rs370731634; called by muse, mutect2, varscan2
- VPS26A | c.170A>C p.K57T | Missense Mutation (SNP) | VAF 29/246 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as rs773159591; called by muse, mutect2, varscan2
- WDFY4 | c.1430G>A p.S477N | Missense Mutation (SNP) | VAF 66/446 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1175589112; called by muse, mutect2, varscan2
- WDFY4 | c.2009G>A p.G670E | Missense Mutation (SNP) | VAF 122/445 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57445777; called by muse, mutect2, varscan2
- WDR59 | c.2507C>T p.P836L | Missense Mutation (SNP) | VAF 134/404 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.443); catalogued as rs186879295, COSV50944455; called by muse, mutect2, varscan2
- WDR87 | c.5430G>A p.M1810I | Missense Mutation (SNP) | VAF 52/397 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs866458488; called by muse, mutect2, varscan2
- WHRN | c.1886C>T p.P629L | Missense Mutation (SNP) | VAF 187/698 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as rs752516364; called by muse, mutect2, varscan2
- WIZ | c.3931G>A p.E1311K (on ENST00000673675 / NM_001371589.1; = p.E216K on NM_021241.3) | Missense Mutation (SNP) | VAF 80/542 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs749432380; called by muse, mutect2, varscan2
- WNT10B | c.916G>A p.G306R | Missense Mutation (SNP) | VAF 125/570 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.012); catalogued as rs918034601; called by muse, mutect2, varscan2
- XIRP2 | c.2263G>A p.E755K (on ENST00000628543; = p.E930K on NM_152381.6) | Missense Mutation (SNP) | VAF 129/418 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); catalogued as rs865872662, COSV54728859; called by muse, mutect2, varscan2
- XIRP2 | c.6004G>A p.D2002N (on ENST00000628543; = p.D2177N on NM_152381.6) | Missense Mutation (SNP) | VAF 151/434 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs113038974; called by muse, mutect2, varscan2
- XKR6 | c.1876C>T p.R626* | Nonsense Mutation (SNP) | VAF 123/519 reads (24%) | catalogued as rs1429331560, COSV58655627; called by muse, mutect2, varscan2
- YLPM1 | c.4039C>T p.R1347W | Missense Mutation (SNP) | VAF 55/391 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.9); catalogued as rs755105593, COSV53107830; called by muse, mutect2, varscan2
- YLPM1 | c.5053C>T p.R1685C | Missense Mutation (SNP) | VAF 30/248 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs375972308; called by muse, mutect2, varscan2
- ZBED9 | c.978G>A p.M326I | Missense Mutation (SNP) | VAF 148/602 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.775); catalogued as rs755344120; called by muse, mutect2, varscan2
- ZBTB7C | c.1703G>A p.R568K | Missense Mutation (SNP) | VAF 240/847 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); catalogued as rs1420455870; called by muse, mutect2, varscan2
- ZFHX2 | c.4880G>A p.R1627Q | Missense Mutation (SNP) | VAF 86/521 reads (17%) | SIFT tolerated (0.98); PolyPhen benign (0.009); catalogued as rs954435481; called by muse, mutect2, varscan2
- ZFP36L2 | c.944C>T p.P315L | Missense Mutation (SNP) | VAF 142/652 reads (22%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.038); catalogued as rs1017746835; called by muse, varscan2
- ZFPM2 | c.3208G>A p.E1070K | Missense Mutation (SNP) | VAF 148/463 reads (32%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.103); catalogued as rs759676967, COSV65874572; called by muse, mutect2, varscan2
- ZNF22 | c.625C>T p.P209S | Missense Mutation (SNP) | VAF 128/426 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs780500522, COSV53584107; called by muse, mutect2, varscan2
- ZNF233 | c.1931G>A p.G644E | Missense Mutation (SNP) | VAF 246/561 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.863); catalogued as rs200527384; called by muse, mutect2, varscan2
- ZNF236 | c.2401G>A p.E801K | Missense Mutation (SNP) | VAF 198/651 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as rs373428289; called by muse, varscan2
- ZNF257 | c.346G>A p.G116S | Missense Mutation (SNP) | VAF 51/371 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as rs1400182477; called by muse, mutect2, varscan2
- ZNF334 | c.1270C>T p.R424* | Nonsense Mutation (SNP) | VAF 104/437 reads (24%) | catalogued as rs143794973; called by muse, mutect2, varscan2
- ZNF350 | c.34G>A p.D12N | Missense Mutation (SNP) | VAF 35/281 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769246022; called by muse, mutect2, varscan2
- ZNF354C | c.638G>A p.G213E | Missense Mutation (SNP) | VAF 125/527 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59607390; called by muse, mutect2, varscan2
- ZNF536 | c.2920G>A p.E974K | Missense Mutation (SNP) | VAF 216/531 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs267605407, COSV62820667; called by muse, mutect2, varscan2
- ZNF541 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 109/558 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs111426088; called by muse, mutect2, varscan2
- ZNF582 | c.1165C>T p.H389Y | Missense Mutation (SNP) | VAF 76/555 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56733873; called by muse, mutect2, varscan2
- ZNF585B | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 42/288 reads (15%) | SIFT tolerated (0.73); PolyPhen benign (0.039); catalogued as rs552277190, COSV57215715; called by muse, mutect2, varscan2
- ZNF606 | c.26C>T p.S9F | Missense Mutation (SNP) | VAF 166/458 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV100008557; called by muse, mutect2, varscan2
- ZNF648 | c.296G>A p.G99E | Missense Mutation (SNP) | VAF 97/466 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV100374812; called by muse, mutect2, varscan2
- ZNF658 | c.2894C>T p.S965F | Missense Mutation (SNP) | VAF 110/457 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs1282227145; called by muse, mutect2, varscan2
- ZNF676 | c.1522C>T p.P508S (on ENST00000650058; = p.P476S on NM_001001411.3) | Missense Mutation (SNP) | VAF 60/500 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV68092195; called by muse, mutect2, varscan2
- ZNF717 | c.1667C>G p.T556S | Missense Mutation (SNP) | VAF 116/477 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.32); catalogued as rs1159819157; called by muse, mutect2, varscan2
- ZNF730 | c.1049A>C p.N350T | Missense Mutation (SNP) | VAF 54/453 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.323); catalogued as COSV74168187; called by muse, mutect2
- ZNF735 | c.578C>T p.S193L | Missense Mutation (SNP) | VAF 73/298 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as COSV70034480; called by muse, mutect2, varscan2
- ZNF786 | c.1697C>T p.S566L | Missense Mutation (SNP) | VAF 191/700 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.146); catalogued as rs1024499674, COSV100302861; called by muse, mutect2, varscan2
- ZNF800 | c.1388C>T p.P463L | Missense Mutation (SNP) | VAF 169/623 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs756238204, COSV56173749; called by muse, mutect2, varscan2
- ZNF813 | c.1648C>T p.P550S | Missense Mutation (SNP) | VAF 62/462 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.433); catalogued as COSV67178726; called by muse, varscan2
- ZNF835 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 92/609 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs780384260, COSV73379802; called by muse, mutect2, varscan2
- ZNF841 | c.910C>T p.H304Y (on ENST00000426391 / NM_001369830.1; = p.H420Y on NM_001136499.1 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 75/538 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV63471734; called by muse, mutect2, varscan2
- ZNRF4 | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 196/550 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs781392658; called by muse, mutect2, varscan2
- ZPBP | c.49C>T p.R17W | Missense Mutation (SNP) | VAF 134/505 reads (27%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs991807385, COSV99250397; called by muse, mutect2, varscan2
- ZSCAN5B | c.922C>T p.Q308* | Nonsense Mutation (SNP) | VAF 72/623 reads (12%) | catalogued as COSV62001238; called by muse, mutect2, varscan2
- AADACL2 | c.188C>A p.S63Y | Missense Mutation (SNP) | VAF 82/346 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- ABCA2 | c.4528C>T p.P1510S (on ENST00000614293; = p.P1480S on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 119/405 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ABCC1 | c.944A>G p.K315R | Missense Mutation (SNP) | VAF 85/521 reads (16%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- ABCC10 | c.503C>T p.P168L (on ENST00000372530 / NM_001198934.2; = p.P125L on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 125/600 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ABHD17B | c.401C>T p.S134F | Missense Mutation (SNP) | VAF 120/442 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- ACAN | c.4899T>A p.Y1633* | Nonsense Mutation (SNP) | VAF 157/456 reads (34%) | called by muse, mutect2, varscan2
- ACIN1 | c.3007C>T p.P1003S | Missense Mutation (SNP) | VAF 49/334 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ACRBP | c.1417C>T p.P473S | Missense Mutation (SNP) | VAF 67/299 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- ACSM2A | c.964G>A p.D322N (on ENST00000219054; = p.D243N on NM_001308169.2) | Missense Mutation (SNP) | VAF 85/329 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- ACSM3 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 50/380 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ACTR5 | c.776-1G>A p.X259_splice | Splice Site (SNP) | VAF 51/208 reads (25%) | called by muse, mutect2
- ACVR1C | c.461del p.P154Hfs*8 | Frame Shift Del (DEL) | VAF 150/556 reads (27%) | called by mutect2, pindel, varscan2
- ADAM22 | c.2146C>T p.P716S | Missense Mutation (SNP) | VAF 92/337 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- ADAMTS20 | c.2650G>A p.D884N | Missense Mutation (SNP) | VAF 98/387 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ADAMTS9 | c.4158G>A p.W1386* | Nonsense Mutation (SNP) | VAF 65/212 reads (31%) | called by muse, mutect2, varscan2
- ADAMTSL5 | c.626T>G p.V209G | Missense Mutation (SNP) | VAF 50/267 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- ADCY1 | c.682G>C p.G228R | Missense Mutation (SNP) | VAF 128/482 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ADCY1 | c.683G>A p.G228E | Missense Mutation (SNP) | VAF 129/484 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRA1 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 71/458 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADGRB1 | c.3496C>T p.Q1166* | Nonsense Mutation (SNP) | VAF 107/546 reads (20%) | called by muse, varscan2
- ADGRB1 | c.4352C>G p.P1451R | Missense Mutation (SNP) | VAF 200/584 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- ADGRL2 | c.1924G>A p.D642N (on ENST00000370717 / NM_001366005.1; = p.D629N on NM_012302.4) | Missense Mutation (SNP) | VAF 104/413 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRV1 | c.17471T>C p.V5824A | Missense Mutation (SNP) | VAF 92/317 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ADH1B | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 146/602 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- AFAP1L2 | c.1843A>G p.I615V | Missense Mutation (SNP) | VAF 70/449 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- AFF2 | c.2125G>A p.E709K | Missense Mutation (SNP) | VAF 140/423 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AGBL4 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 122/339 reads (36%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- AGO2 | c.2461G>A p.E821K | Missense Mutation (SNP) | VAF 79/385 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- AKAP11 | c.1032T>A p.D344E | Missense Mutation (SNP) | VAF 102/323 reads (32%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- AKAP11 | c.1705T>A p.L569I | Missense Mutation (SNP) | VAF 120/380 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- AKR1D1 | c.892G>A p.D298N | Missense Mutation (SNP) | VAF 89/375 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALX1 | c.944C>T p.A315V | Missense Mutation (SNP) | VAF 115/451 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AMPD3 | c.1918T>C p.F640L (on ENST00000396553 / NM_001025389.2; = p.F649L on NM_000480.3) | Missense Mutation (SNP) | VAF 146/417 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- ANAPC13 | c.14T>C p.V5A | Missense Mutation (SNP) | VAF 96/412 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANK3 | c.9487G>A p.G3163R | Missense Mutation (SNP) | VAF 133/407 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- ANKIB1 | c.2489A>G p.D830G | Missense Mutation (SNP) | VAF 113/464 reads (24%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANKK1 | c.2007G>T p.R669S | Missense Mutation (SNP) | VAF 85/471 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- ANKRD30B | c.1429T>C p.F477L | Missense Mutation (SNP) | VAF 73/255 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- ANKRD31 | c.5483C>T p.S1828F | Missense Mutation (SNP) | VAF 105/294 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- APLP1 | c.428G>A p.G143D | Missense Mutation (SNP) | VAF 30/276 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APOB | c.11030T>C p.L3677P | Missense Mutation (SNP) | VAF 169/498 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- APOBEC1 | c.29G>C p.G10A | Missense Mutation (SNP) | VAF 72/395 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ARAP3 | c.343G>T p.G115W | Missense Mutation (SNP) | VAF 178/723 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARC | c.13C>T p.H5Y | Missense Mutation (SNP) | VAF 151/430 reads (35%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- ARID1A | c.3001T>G p.S1001A | Missense Mutation (SNP) | VAF 80/291 reads (27%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- ASPM | c.3179C>T p.S1060F | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT tolerated (0.78); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- ATP1A3 | c.1432A>C p.K478Q (on ENST00000545399 / NM_001256214.2; = p.K465Q on NM_152296.5) | Missense Mutation (SNP) | VAF 51/459 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ATP2A2 | c.293T>C p.L98S | Missense Mutation (SNP) | VAF 103/300 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP6V0D2 | c.185C>T p.T62I | Missense Mutation (SNP) | VAF 108/328 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- ATP9A | c.2516C>T p.S839L | Missense Mutation (SNP) | VAF 143/550 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
1,268 further variants in this file (564 protein-altering or splice-affecting, 633 silent, 71 other) are not listed here.
